Somatic mutation profile of tumor specimen TCGA-44-2656-01A (aliquot TCGA-44-2656-01A-41D-A27T-08) from TCGA case TCGA-44-2656, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 59.6 years (21,766 days).
Specimen TCGA-44-2656-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7ee3e85-75fb-4fe9-ae51-97d149781b26.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-2656-10A (Blood Derived Normal), aliquot TCGA-44-2656-10A-01D-0969-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6bd62e34-5534-4ee0-b69b-c40ab757489d

The open-access MAF lists 918 somatic variants for this specimen: 701 protein-altering or splice-affecting, 199 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 579, Silent 199, Nonsense Mutation 63, Splice Site 26, Frame Shift Del 15, Splice Region 10, Intron 7, RNA 7, Frame Shift Ins 6, 3'UTR 2, In Frame Del 1, 5'UTR 1.

Variants (750 of 918; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 100/333 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AADACL2 | c.786G>A p.W262* | Nonsense Mutation (SNP) | VAF 46/157 reads (29%) | catalogued as COSV62929677; called by muse, mutect2, varscan2
- ABCA10 | c.3577G>T p.E1193* | Nonsense Mutation (SNP) | VAF 9/59 reads (15%) | catalogued as COSV52218722; called by muse, mutect2, varscan2
- ABCA13 | c.12366G>T p.K4122N | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV71284197; called by muse, mutect2, varscan2
- ABCA4 | c.426C>A p.H142Q | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as COSV64671523; called by muse, mutect2, varscan2
- ABCA9 | c.661G>T p.V221F | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV60621424, COSV60627170; called by muse, mutect2, varscan2
- ABCC9 | c.52G>C p.G18R | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as COSV53964291; called by muse, mutect2, varscan2
- AC105001.2 | c.178G>T p.V60L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.121); catalogued as COSV59108476; called by muse, mutect2
- ACSL1 | c.724G>T p.G242W | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55661049, COSV55666266; called by muse, mutect2, varscan2
- ACTG1 | c.136G>T p.G46C | Missense Mutation (SNP) | VAF 72/224 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.745); catalogued as COSV59509545, COSV59509810; called by muse, varscan2
- ADAM12 | c.1436G>T p.G479V | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64103177, COSV64103261; called by muse, mutect2, varscan2
- ADAM20 | c.285G>T p.Q95H | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV56454240; called by muse, mutect2, varscan2
- ADAMTS15 | c.1726G>A p.G576R | Missense Mutation (SNP) | VAF 23/429 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs147190472; called by muse, mutect2
- ADAMTS16 | c.3591C>A p.C1197* | Nonsense Mutation (SNP) | VAF 19/40 reads (48%) | catalogued as COSV56980510; called by muse, mutect2, varscan2
- ADCY5 | c.1909A>T p.I637F | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV59194995; called by muse, mutect2, varscan2
- ADCY6 | c.1495G>T p.V499L | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57166513; called by muse, mutect2, varscan2
- ADGRG4 | c.3931C>T p.Q1311* | Nonsense Mutation (SNP) | VAF 46/102 reads (45%) | catalogued as rs1433246655, COSV54950883; called by muse, mutect2, varscan2
- ADGRL4 | c.844T>A p.F282I | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV66059758; called by muse, mutect2, varscan2
- AFF2 | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 98/242 reads (40%) | catalogued as COSV60656743, COSV60659025; called by muse, mutect2, varscan2
- AFF4 | c.400C>T p.Q134* | Nonsense Mutation (SNP) | VAF 30/86 reads (35%) | catalogued as COSV54792178; called by muse, mutect2, varscan2
- AGL | c.790G>T p.G264W | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54048722, COSV54054032; called by muse, mutect2, varscan2
- AGO3 | c.399G>T p.W133C | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV55791675; called by muse, mutect2, varscan2
- AHNAK | c.8602G>T p.E2868* | Nonsense Mutation (SNP) | VAF 9/229 reads (4%) | catalogued as COSV57205592, COSV57221348; called by muse, mutect2
- AHNAK2 | c.14074G>A p.E4692K | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV60909243; called by muse, mutect2
- AHNAK2 | c.2839G>T p.G947C | Missense Mutation (SNP) | VAF 67/483 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV60909246; called by muse, mutect2, varscan2
- ALDH1L1 | c.1480G>T p.D494Y | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56411309; called by muse, mutect2, varscan2
- ALK | c.1359G>T p.Q453H | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV66559553; called by muse, mutect2, varscan2
- ALOX5 | c.437T>A p.M146K | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65551322; called by muse, mutect2, varscan2
- ALPK2 | c.3485C>A p.A1162D | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as COSV100864754, COSV64490735; called by muse, mutect2, varscan2
- ALPK2 | c.884C>G p.P295R | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.101); catalogued as COSV64490743; called by muse, mutect2, varscan2
- AMPD2 | c.442G>T p.E148* | Nonsense Mutation (SNP) | VAF 8/62 reads (13%) | catalogued as COSV56646529; called by muse, mutect2, varscan2
- AP2A2 | c.2555A>T p.Q852L | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV59958409; called by muse, mutect2, varscan2
- APIP | c.57G>T p.Q19H | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV53506143; called by muse, mutect2, varscan2
- APOB | c.2617C>A p.L873M | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV51925712; called by muse, mutect2, varscan2
- APOBEC4 | c.41C>T p.T14I | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58016983; called by muse, mutect2, varscan2
- APOBR | c.2839G>T p.A947S (on ENST00000431282; = p.A956S on NM_018690.4) | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs1486024392, COSV60489064; called by muse, mutect2, varscan2
- ARFIP1 | c.567G>T p.M189I (on ENST00000353617 / NM_001287432.1; = p.M157I on NM_014447.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.017); catalogued as COSV61883385, COSV61886434; called by muse, mutect2, varscan2
- ARHGAP25 | c.1380C>A p.S460R (on ENST00000409202 / NM_001007231.3; = p.S452R on NM_014882.3) | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.348); catalogued as COSV54899273; called by muse, mutect2, varscan2
- ARHGAP33 | c.1814G>A p.R605Q | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.648); catalogued as rs139022184; called by muse, mutect2, varscan2
- ARMC5 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV51655112; called by muse, mutect2
- ARMC5 | c.1085G>C p.R362P | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51655120, COSV51659726; called by muse, mutect2, varscan2
- ARSF | c.746G>C p.R249P | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63839074; called by muse, mutect2, varscan2
- ASB15 | c.323C>A p.T108N | Missense Mutation (SNP) | VAF 38/169 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV99306291; called by muse, mutect2, varscan2
- ASPM | c.8315A>G p.Q2772R | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV54125763; called by muse, mutect2, varscan2
- ASXL3 | c.3416C>A p.P1139H | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as COSV99323798; called by muse, mutect2, varscan2
- ATP13A2 | c.3034G>T p.V1012L | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.046); catalogued as COSV58698526; called by muse, mutect2, varscan2
- ATP1A3 | c.2892G>T p.E964D (on ENST00000545399 / NM_001256214.2; = p.E951D on NM_152296.5) | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as COSV57485662; called by muse, mutect2, varscan2
- ATP1B4 | c.844A>G p.I282V (on ENST00000218008 / NM_001142447.3; = p.I278V on NM_012069.5) | Missense Mutation (SNP) | VAF 105/207 reads (51%) | SIFT tolerated (0.72); PolyPhen benign (0.02); catalogued as COSV54311501; called by muse, mutect2, varscan2
- ATP2A1 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV63920115; called by muse, mutect2, varscan2
- ATP2B3 | c.1206G>A p.W402* | Nonsense Mutation (SNP) | VAF 9/61 reads (15%) | catalogued as COSV54841452; called by muse, mutect2, varscan2
- ATP4A | c.2542C>A p.R848S | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52866115; called by muse, mutect2, varscan2
- ATXN1 | c.490G>T p.G164W | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.647); catalogued as COSV55207197, COSV55209691; called by muse, mutect2, varscan2
- BCAS1 | c.1153G>C p.D385H | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV65084225; called by muse, mutect2
- BCAS1 | c.811G>T p.A271S | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.669); catalogued as COSV65084231; called by muse, mutect2, varscan2
- BDP1 | c.1961A>T p.H654L | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as rs754948193, COSV62429287; called by muse, mutect2, varscan2
- BICD1 | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55675492, COSV55683113; called by muse, mutect2, varscan2
- BIN2 | c.745G>C p.V249L | Missense Mutation (SNP) | VAF 81/219 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.213); catalogued as COSV57203914; called by muse, mutect2, varscan2
- BLOC1S4 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.371); catalogued as COSV57900861, COSV57901018; called by muse, mutect2
- BORA | c.853T>A p.S285T (on ENST00000613797; = p.S210T on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.709); catalogued as COSV64694931; called by muse, mutect2, varscan2
- BRAT1 | c.881A>G p.H294R | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV61394381; called by muse, mutect2, varscan2
- BRINP3 | c.2026G>C p.D676H | Missense Mutation (SNP) | VAF 41/192 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66515010; called by muse, mutect2, varscan2
- BRIP1 | c.3601A>G p.I1201V | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as rs1396175226, COSV51994991; called by muse, mutect2, varscan2
- BUB1B | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs587778144, COSV55010377; ClinVar: not provided; called by muse, mutect2, varscan2
- C22orf42 | c.295C>A p.L99I | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated, low confidence (0.51); PolyPhen possibly damaging (0.567); catalogued as COSV66075359; called by muse, mutect2, varscan2
- C2orf78 | c.1831C>A p.Q611K | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.52); catalogued as COSV68516564; called by muse, mutect2, varscan2
- C8B | c.1119C>A p.N373K | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV64776652; called by muse, mutect2, varscan2
- C8orf58 | c.427A>T p.K143* | Nonsense Mutation (SNP) | VAF 4/21 reads (19%) | catalogued as COSV99254483; called by muse, mutect2, varscan2
- C9orf64 | c.490G>T p.G164* | Nonsense Mutation (SNP) | VAF 29/126 reads (23%) | catalogued as COSV59032188; called by muse, mutect2, varscan2
- CACNA1E | c.1924A>C p.T642P | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62384172; called by muse, mutect2, varscan2
- CACNA1E | c.5791G>T p.G1931C | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV62383371, COSV62384187; called by muse, mutect2, varscan2
- CADPS | c.1137C>G p.I379M | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as COSV51869717; called by muse, mutect2, varscan2
- CALU | c.332G>T p.R111L | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV50823286, COSV99975725; called by muse, mutect2, varscan2
- CAMK2A | c.158-1G>T p.X53_splice | Splice Site (SNP) | VAF 7/44 reads (16%) | catalogued as COSV62245306; called by muse, mutect2, varscan2
- CAMK4 | c.452C>A p.A151E | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56663808; called by muse, mutect2
- CARD11 | c.258G>T p.R86S | Missense Mutation (SNP) | VAF 46/357 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62716163, COSV62716582; called by muse, varscan2
- CARMIL2 | c.544G>T p.D182Y | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100575991; called by muse, mutect2, varscan2
- CCDC102B | c.1183G>C p.D395H | Missense Mutation (SNP) | VAF 24/203 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as COSV60135607, COSV60140723; called by muse, mutect2, varscan2
- CCDC136 | c.1894C>A p.Q632K | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV52796854; called by muse, mutect2, varscan2
- CCDC171 | c.2564A>C p.K855T | Missense Mutation (SNP) | VAF 48/198 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV52634882; called by muse, mutect2, varscan2
- CCDC63 | c.1222G>T p.D408Y | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); catalogued as COSV57527263; called by muse, mutect2, varscan2
- CCDC9B | c.998G>A p.R333K | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66874819; called by muse, mutect2, varscan2
- CCNO | c.1027T>C p.C343R | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.526); catalogued as rs750464287, COSV57004411; called by muse, mutect2, varscan2
- CCT8L2 | c.1539G>C p.Q513H | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.381); catalogued as COSV63461753, COSV63464025; called by muse, mutect2, varscan2
- CD101 | c.239T>C p.F80S | Missense Mutation (SNP) | VAF 5/118 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99869233; called by muse, mutect2
- CD163 | c.2960G>T p.G987V | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100775730, COSV63131323; called by muse, mutect2, varscan2
- CD163 | c.2959G>T p.G987W | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100775731; called by muse, mutect2, varscan2
- CD244 | c.785C>A p.T262N (on ENST00000368033 / NM_001166663.2; = p.T257N on NM_016382.4) | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.222); catalogued as rs1377239214, COSV59236441; called by muse, mutect2, varscan2
- CD244 | c.403G>T p.E135* (on ENST00000368033 / NM_001166663.2; = p.E130* on NM_016382.4) | Nonsense Mutation (SNP) | VAF 31/141 reads (22%) | catalogued as COSV59236463, COSV59237862; called by muse, mutect2, varscan2
- CD5L | c.895A>T p.K299* | Nonsense Mutation (SNP) | VAF 55/178 reads (31%) | catalogued as COSV63821247; called by muse, mutect2, varscan2
- CD6 | c.1364T>C p.V455A | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.232); catalogued as COSV57836214; called by muse, mutect2, varscan2
- CDC73 | c.709A>G p.I237V | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0.045); catalogued as COSV66465322; called by muse, mutect2
- CDH1 | c.1378G>T p.V460L | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV55728592; called by muse, mutect2, varscan2
- CDH24 | c.2149C>T p.P717S | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.129); catalogued as rs1171193219, COSV57458935; called by muse, mutect2
- CDH6 | c.613C>G p.Q205E | Missense Mutation (SNP) | VAF 12/137 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.874); catalogued as COSV54065290; called by muse, mutect2
- CEACAM18 | c.682G>C p.D228H | Missense Mutation (SNP) | VAF 92/267 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV67282317, COSV67283582; called by muse, mutect2, varscan2
- CEP126 | c.15G>T p.R5S | Missense Mutation (SNP) | VAF 103/231 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.668); catalogued as COSV54822265; called by muse, mutect2, varscan2
- CFAP299 | c.601C>A p.P201T | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63871884; called by muse, mutect2, varscan2
- CFAP57 | c.133C>A p.Q45K | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as COSV52539439; called by muse, mutect2, varscan2
- CFHR4 | c.249C>A p.C83* (on ENST00000367416 / NM_001201551.2; = p.C84* on NM_006684.5) | Nonsense Mutation (SNP) | VAF 65/194 reads (34%) | catalogued as COSV52225316; called by muse, mutect2, varscan2
- CFHR5 | c.1145C>A p.T382K | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV56818614; called by muse, mutect2, varscan2
- CHD6 | c.3275A>T p.Y1092F | Missense Mutation (SNP) | VAF 8/177 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.909); catalogued as COSV58554481; called by muse, mutect2
- CHST13 | c.137G>C p.G46A | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.473); catalogued as COSV60041502; called by muse, mutect2, varscan2
- CHST2 | c.895C>G p.R299G | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV58884824; called by muse, mutect2, varscan2
- CIB4 | c.197T>A p.F66Y | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56599510; called by muse, mutect2, varscan2
- CIC | c.1387A>G p.I463V | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.93); catalogued as COSV50549051; called by muse, mutect2, varscan2
- CIP2A | c.1924G>T p.D642Y | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55417434; called by muse, mutect2, varscan2
- CIT | c.841G>T p.G281C | Missense Mutation (SNP) | VAF 70/161 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV55861941; called by muse, mutect2, varscan2
- CLASP1 | c.4265A>T p.Q1422L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.034); catalogued as COSV55315566; called by muse, mutect2, varscan2
- CLASRP | c.697G>C p.G233R | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); catalogued as COSV99673595; called by muse, mutect2, varscan2
- CLCN4 | c.1016G>C p.G339A | Missense Mutation (SNP) | VAF 17/190 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66465375; called by muse, mutect2, varscan2
- CLDN14 | c.414G>T p.W138C | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59772018; called by muse, mutect2, varscan2
- CNGB3 | c.1179-1G>T p.X393_splice | Splice Site (SNP) | VAF 22/70 reads (31%) | catalogued as COSV60685706; called by muse, mutect2, varscan2
- CNOT1 | c.1041A>T p.E347D | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as COSV57765739; called by muse, mutect2, varscan2
- CNTN2 | c.2914C>A p.P972T | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as COSV59348479; called by muse, mutect2, varscan2
- CNTN4 | c.631C>A p.P211T | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV61868879; called by muse, mutect2, varscan2
- CNTNAP2 | c.1870C>A p.P624T | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV62150646; called by muse, mutect2, varscan2
- CNTNAP4 | c.1150C>A p.P384T | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs762920106, COSV100269809; called by muse, mutect2, varscan2
- CNTNAP4 | c.1151C>G p.P384R | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV100269812; called by muse, mutect2, varscan2
- CNTNAP5 | c.3214G>A p.G1072R | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs772641478, COSV70475477; called by muse, mutect2, varscan2
- COBL | c.2142G>T p.K714N | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV54339812; called by muse, mutect2, varscan2
- COL11A1 | c.4985C>A p.S1662* | Nonsense Mutation (SNP) | VAF 12/70 reads (17%) | catalogued as COSV62174875, COSV62191256; called by muse, mutect2, varscan2
- COL15A1 | c.3032-1G>T p.X1011_splice | Splice Site (SNP) | VAF 25/257 reads (10%) | catalogued as COSV66641776; called by muse, mutect2, varscan2
- COL22A1 | c.421G>C p.A141P | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.863); catalogued as COSV100276821, COSV57349058; called by muse, mutect2, varscan2
- COL25A1 | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67647040; called by muse, mutect2
- COL27A1 | c.3338C>T p.P1113L | Missense Mutation (SNP) | VAF 38/184 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV61922285; called by muse, mutect2, varscan2
- COL3A1 | c.282+1G>T p.X94_splice | Splice Site (SNP) | VAF 15/45 reads (33%) | catalogued as COSV58582976; called by muse, mutect2, varscan2
- COL4A2 | c.2704G>T p.G902* | Nonsense Mutation (SNP) | VAF 17/93 reads (18%) | catalogued as COSV64625481; called by muse, mutect2, varscan2
- COL4A2 | c.4585C>A p.Q1529K | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100847267; called by muse, mutect2, varscan2
- COL5A1 | c.1774G>T p.G592C | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65665879; called by muse, mutect2, varscan2
- COL5A1 | c.2148G>T p.E716D | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV65665882; called by muse, mutect2, varscan2
- COL5A2 | c.3797C>T p.P1266L | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.781); catalogued as COSV100880708, COSV66407652; called by muse, mutect2, varscan2
- COL9A3 | c.1056C>A p.G352= | Splice Region (SNP) | VAF 7/25 reads (28%) | catalogued as COSV59650849; called by muse, mutect2, varscan2
- CPEB1 | c.1621C>T p.Q541* (on ENST00000617958; = p.Q476* on NM_030594.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 24/71 reads (34%) | catalogued as COSV55617442; called by muse, mutect2, varscan2
- CPED1 | c.2839C>A p.Q947K | Missense Mutation (SNP) | VAF 47/200 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV100120269; called by muse, mutect2, varscan2
- CRACD | c.2737G>T p.A913S | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.033); catalogued as COSV51716175; called by muse, mutect2, varscan2
- CREB3L2 | c.494G>T p.G165V | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.086); catalogued as COSV57792636; called by muse, mutect2, varscan2
- CRISPLD1 | c.1231T>A p.S411T | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV51544994; called by muse, mutect2
- CRISPLD2 | c.998G>C p.R333P | Missense Mutation (SNP) | VAF 43/218 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52277138; called by muse, mutect2, varscan2
- CROT | c.1064G>T p.G355V | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58973012; called by muse, mutect2, varscan2
- CSMD1 | c.6664G>T p.A2222S (on ENST00000520002; = p.A2221S on NM_033225.6) | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV59289735, COSV59300282; called by muse, mutect2
- CSMD2 | c.9173G>T p.W3058L | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53885674; called by muse, mutect2, varscan2
- CSMD2 | c.1918G>T p.A640S | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (0.8); PolyPhen benign (0.074); catalogued as COSV53885699, COSV53897184; called by muse, mutect2
- CSMD3 | c.10628G>T p.G3543V (on ENST00000297405 / NM_001363185.1; = p.G3374V on NM_052900.3) | Missense Mutation (SNP) | VAF 24/207 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52115921, COSV99834043; called by muse, mutect2, varscan2
- CSMD3 | c.4107A>T p.Q1369H (on ENST00000297405 / NM_001363185.1; = p.Q1265H on NM_052900.3) | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.981); catalogued as COSV52116030; called by muse, mutect2, varscan2
- CSMD3 | c.1116C>A p.S372R | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV52116072; called by muse, mutect2, varscan2
- CSN3 | c.100G>C p.D34H | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as COSV59243600; called by muse, mutect2, varscan2
- CT83 | c.137C>A p.S46Y | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV64140819; called by muse, mutect2, varscan2
- CTNNA2 | c.2154G>T p.M718I | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV100559222, COSV58138215; called by muse, mutect2, varscan2
- CTNND2 | c.1418G>T p.G473V | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as COSV58869546; called by muse, mutect2, varscan2
- CUBN | c.10429C>A p.P3477T | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1468596216, COSV64709163; called by muse, mutect2, varscan2
- CUX2 | c.2417C>T p.S806L | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.988); catalogued as rs1445106287, COSV55625959; called by muse, mutect2, varscan2
- CYP4F3 | c.552G>T p.E184D | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV55407556; called by muse, mutect2, varscan2
- DCAF8L1 | c.101C>A p.A34E | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV71595155; called by muse, mutect2, varscan2
- DCUN1D1 | c.295A>G p.S99G | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as COSV53043841; called by muse, mutect2
- DDC | c.570G>T p.Q190H | Missense Mutation (SNP) | VAF 68/263 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV63564084; called by muse, mutect2, varscan2
- DEPDC7 | c.1263G>A p.K421= (on ENST00000241051 / NM_001077242.2; = p.K412= on NM_139160.2) | Splice Region (SNP) | VAF 42/158 reads (27%) | catalogued as COSV53806054; called by muse, mutect2, varscan2
- DGKB | c.2281G>T p.E761* | Nonsense Mutation (SNP) | VAF 96/298 reads (32%) | catalogued as COSV51765416; called by muse, mutect2, varscan2
- DIAPH3 | c.1699G>T p.E567* (on ENST00000400324 / NM_001042517.2; = p.E304* on NM_030932.3) | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as COSV99932962; called by muse, mutect2
- DIO2 | c.512C>A p.A171E | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as rs766090858, COSV70444863, COSV70445145; called by muse, mutect2, varscan2
- DIP2C | c.2554G>A p.E852K | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV55148506; called by muse, mutect2, varscan2
- DISP3 | c.1415G>A p.C472Y | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1263650241, COSV53821782; called by muse, mutect2
- DISP3 | c.3376-1G>T p.X1126_splice | Splice Site (SNP) | VAF 31/121 reads (26%) | catalogued as COSV53821800; called by muse, mutect2, varscan2
- DLL3 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 62/171 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.38); catalogued as COSV52693610; called by muse, mutect2, varscan2
- DNAH9 | c.9245A>T p.Q3082L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52337591; called by muse, mutect2
- DNER | c.1246T>C p.C416R | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59161139; called by muse, mutect2, varscan2
- DSCAM | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.434); catalogued as rs373921750; called by muse, mutect2
- DSCAML1 | c.1894G>T p.E632* (on ENST00000321322; = p.E572* on NM_020693.4) | Nonsense Mutation (SNP) | VAF 28/74 reads (38%) | catalogued as COSV58383444; called by muse, mutect2, varscan2
- DSEL | c.3485C>T p.A1162V | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as COSV59489816; called by muse, mutect2, varscan2
- DSG3 | c.1457C>A p.P486H | Missense Mutation (SNP) | VAF 20/201 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV57124603; called by muse, mutect2, varscan2
- DUOX1 | c.3085C>A p.Q1029K | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.14); catalogued as COSV58477926; called by muse, mutect2, varscan2
- DUSP22 | c.271G>T p.G91W | Missense Mutation (SNP) | VAF 18/294 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60524272; called by muse, mutect2
- DYNC1H1 | c.6397G>T p.E2133* | Nonsense Mutation (SNP) | VAF 8/55 reads (15%) | catalogued as COSV64134814; called by muse, mutect2, varscan2
- DYRK4 | c.1337A>G p.K446R | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV50537998; called by muse, mutect2
- EBF2 | c.996G>C p.R332S | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as COSV68776392, COSV68779949; called by muse, mutect2, varscan2
- EDA2R | c.264C>T p.P88= | Splice Region (SNP) | VAF 5/9 reads (56%) | catalogued as COSV53630426; called by muse, mutect2, varscan2
- EDIL3 | c.1398G>C p.R466S | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.918); catalogued as COSV56882919; called by muse, mutect2, varscan2
- EDN3 | c.251C>A p.A84E | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs142051051, COSV61107321; called by muse, mutect2, varscan2
- EIF4A2 | c.976G>T p.V326F | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV56215789; called by muse, mutect2, varscan2
- ELF1 | c.1537C>G p.Q513E | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.137); catalogued as COSV53497380; called by muse, mutect2, varscan2
- ELF2 | c.599C>G p.P200R (on ENST00000379550 / NM_001331036.2; = p.P140R on NM_006874.4) | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV55491915; called by muse, mutect2, varscan2
- EMILIN2 | c.1090G>T p.G364* | Nonsense Mutation (SNP) | VAF 24/107 reads (22%) | catalogued as COSV54421597; called by muse, mutect2, varscan2
- ENAH | c.1432G>T p.E478* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | catalogued as COSV52865586, COSV52868416; called by muse, mutect2
- EPHA5 | c.2188C>A p.Q730K | Missense Mutation (SNP) | VAF 41/232 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56633773; called by muse, mutect2, varscan2
- EPHA6 | c.711C>A p.N237K | Missense Mutation (SNP) | VAF 91/421 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as COSV67561544; called by muse, mutect2, varscan2
- EPHA7 | c.2500G>A p.E834K | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65178175; called by muse, mutect2, varscan2
- EPX | c.171-2A>T p.X57_splice | Splice Site (SNP) | VAF 45/266 reads (17%) | catalogued as COSV56595278; called by muse, mutect2, varscan2
- EPYC | c.899C>A p.P300H | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53798686, COSV53800095; called by muse, mutect2, varscan2
- ERG | c.443A>C p.Q148P | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV55727958; called by muse, mutect2
- ERICH3 | c.604-1G>C p.X202_splice | Splice Site (SNP) | VAF 6/90 reads (7%) | catalogued as COSV58600961; called by muse, mutect2
- ETNPPL | c.841G>A p.G281S | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56594815, COSV56595625; called by muse, mutect2, varscan2
- EXT2 | c.1654G>T p.G552C (on ENST00000343631; = p.G585C on NM_000401.3) | Missense Mutation (SNP) | VAF 40/200 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100640528, COSV59146368; called by muse, mutect2, varscan2
- EXT2 | c.1655G>T p.G552V (on ENST00000343631; = p.G585V on NM_000401.3) | Missense Mutation (SNP) | VAF 40/196 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100640529; called by muse, mutect2, varscan2
- F13A1 | c.29G>A p.G10E | Missense Mutation (SNP) | VAF 53/281 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.043); catalogued as COSV53554408; called by muse, mutect2, varscan2
- FAM120A | c.2287G>T p.D763Y | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52901843, COSV99464656; called by muse, mutect2
- FAM171B | c.1189G>T p.V397F | Missense Mutation (SNP) | VAF 92/303 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.767); catalogued as COSV59001183; called by muse, mutect2, varscan2
- FAM47C | c.484G>C p.A162P | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV63724173, COSV63727538; called by muse, mutect2, varscan2
- FAM47C | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.519); catalogued as rs1251517581, COSV63724190; called by muse, mutect2, varscan2
- FAM83C | c.603C>A p.Y201* | Nonsense Mutation (SNP) | VAF 39/126 reads (31%) | catalogued as COSV65582262, COSV65584138; called by muse, mutect2, varscan2
- FBLIM1 | c.577C>T p.R193* | Nonsense Mutation (SNP) | VAF 21/109 reads (19%) | catalogued as rs140794901; called by muse, mutect2, varscan2
- FBXO40 | c.1802T>G p.V601G | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.295); catalogued as COSV57522345; called by muse, mutect2
- FCRL4 | c.917T>A p.L306Q | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54860250; called by muse, mutect2, varscan2
- FCRLA | c.296C>A p.S99Y (on ENST00000367959; = p.S76Y on NM_032738.4) | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99375736; called by muse, varscan2
- FER1L6 | c.4814C>A p.T1605N | Missense Mutation (SNP) | VAF 65/168 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV67548408; called by muse, mutect2, varscan2
- FHDC1 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 58/184 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.796); catalogued as COSV52598100; called by muse, mutect2, varscan2
- FHL1 | c.32G>T p.R11M | Missense Mutation (SNP) | VAF 80/175 reads (46%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.957); catalogued as COSV61779961; called by muse, mutect2, varscan2
- FHL5 | c.757G>T p.G253W | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as COSV58735599; called by muse, mutect2, varscan2
- FLG | c.1882C>G p.Q628E | Missense Mutation (SNP) | VAF 209/663 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.124); catalogued as rs779204654, COSV64237807; called by muse, mutect2, varscan2
- FREM1 | c.4389G>T p.Q1463H | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV66518765; called by muse, mutect2, varscan2
- FRMPD2 | c.922-2A>T p.X308_splice | Splice Site (SNP) | VAF 12/75 reads (16%) | catalogued as COSV59715779; called by muse, mutect2, varscan2
- FRY | c.5921A>T p.E1974V | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.074); catalogued as COSV66566181; called by muse, mutect2
- FSIP2 | c.18260C>A p.S6087Y | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100554334; called by muse, mutect2, varscan2
- FUT8 | c.611G>C p.C204S (on ENST00000360689 / NM_001371534.1; = p.C41S on NM_004480.4) | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61280796; called by muse, mutect2, varscan2
- FYCO1 | c.259G>T p.G87W | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56114071; called by muse, mutect2, varscan2
- GALC | c.1757G>T p.G586V | Missense Mutation (SNP) | VAF 32/284 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54323602; called by muse, mutect2, varscan2
- GANAB | c.1050G>T p.Q350H | Missense Mutation (SNP) | VAF 118/562 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV60462469; called by muse, mutect2, varscan2
- GARNL3 | c.230C>G p.A77G | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV59224143; called by muse, mutect2
- GARNL3 | c.1029-1G>A p.X343_splice | Splice Site (SNP) | VAF 14/94 reads (15%) | catalogued as COSV59224151; called by muse, mutect2, varscan2
- GAS2 | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53404911; called by muse, mutect2, varscan2
- GDNF | c.459G>T p.E153D | Missense Mutation (SNP) | VAF 32/203 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.125); catalogued as COSV58478486; called by muse, mutect2, varscan2
- GJB1 | c.123G>T p.E41D | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as CM066092, COSV62139558; called by muse, mutect2, varscan2
- GLRX3 | c.276+1G>T p.X92_splice | Splice Site (SNP) | VAF 39/113 reads (35%) | catalogued as COSV58691719; called by muse, mutect2, varscan2
- GNAQ | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 61/245 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54108142; called by muse, mutect2, varscan2
- GPC5 | c.249G>T p.Q83H | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.95); catalogued as COSV65581502, COSV65582941; called by muse, mutect2, varscan2
- GPR139 | c.464C>A p.T155N | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.295); catalogued as COSV58501876; called by muse, mutect2
- GPR141 | c.655C>A p.Q219K | Missense Mutation (SNP) | VAF 47/246 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV57731470; called by muse, mutect2, varscan2
- GPR63 | c.700A>C p.T234P | Missense Mutation (SNP) | VAF 51/169 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as rs866908729, COSV57739865; called by muse, mutect2, varscan2
- GPR63 | c.16G>T p.V6L | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0); catalogued as rs1168525347, COSV57739874; called by muse, mutect2, varscan2
- GRID1 | c.919G>T p.D307Y | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV60016391, COSV60052524; called by muse, mutect2, varscan2
- GRIN2D | c.2480T>A p.I827N | Missense Mutation (SNP) | VAF 72/252 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53517920; called by muse, mutect2, varscan2
- GRK2 | c.990C>G p.H330Q | Missense Mutation (SNP) | VAF 16/274 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57950625, COSV57951172; called by muse, mutect2
- GRM8 | c.2096C>A p.T699N | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV58807197; called by muse, mutect2, varscan2
- GRM8 | c.1742C>A p.S581Y | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV58807209, COSV58878853; called by muse, mutect2, varscan2
- GSTZ1 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as rs939750689, COSV53622919; called by muse, mutect2, varscan2
- GTPBP3 | c.115C>G p.L39V | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.951); catalogued as rs746303532, COSV50173654; called by muse, mutect2, varscan2
- HAS2 | c.448A>T p.N150Y | Missense Mutation (SNP) | VAF 31/482 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV58262359; called by muse, mutect2
- HDAC2 | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV64037464; called by muse, mutect2, varscan2
- HDAC4 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV61860646; called by muse, mutect2, varscan2
- HEATR5A | c.4460C>A p.A1487E | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.811); catalogued as rs757014948, COSV66338870; called by muse, mutect2, varscan2
- HECW1 | c.14T>A p.L5Q | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.995); catalogued as COSV67823496; called by muse, mutect2, varscan2
- HEMGN | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.028); catalogued as COSV52325428; called by muse, mutect2
- HEPH | c.1557G>T p.W519C (on ENST00000343002; = p.W252C on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57960018; called by muse, mutect2, varscan2
- HES2 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as COSV64732231; called by muse, mutect2, varscan2
- HHATL | c.1011G>T p.T337= | Splice Region (SNP) | VAF 15/30 reads (50%) | catalogued as COSV55133017; called by muse, mutect2, varscan2
- HMCN1 | c.1247A>G p.Q416R | Missense Mutation (SNP) | VAF 52/156 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV54881632; called by muse, mutect2, varscan2
- HNF4G | c.1104C>A p.I368= (on ENST00000354370 / NM_001330561.2; = p.I415= on NM_004133.5) | Splice Region (SNP) | VAF 12/94 reads (13%) | catalogued as COSV62966208; called by muse, mutect2, varscan2
- HNRNPD | c.777del p.K260Rfs*109 (on ENST00000313899 / NM_031370.3; = p.K260Rfs*60 on NM_002138.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 102/454 reads (22%) | catalogued as COSV100002762; called by mutect2, varscan2
- HOXA1 | c.205C>A p.H69N | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.466); catalogued as COSV56065371; called by muse, mutect2, varscan2
- HOXA2 | c.850C>A p.L284M | Missense Mutation (SNP) | VAF 55/176 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.62); catalogued as rs1278253439, COSV56065380; called by muse, mutect2, varscan2
- HOXA7 | c.136G>C p.A46P | Missense Mutation (SNP) | VAF 45/252 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as COSV54216847, COSV99636727; called by muse, mutect2, varscan2
- HP1BP3 | c.1205G>T p.G402V | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100391598; called by muse, mutect2, varscan2
- HSPH1 | c.2125G>A p.A709T | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.313); catalogued as COSV60710458; called by muse, mutect2
- IFNA2 | c.374G>T p.G125V | Missense Mutation (SNP) | VAF 26/292 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.359); catalogued as COSV66505368, COSV66505777; called by muse, mutect2
- IGFBPL1 | c.506G>T p.G169V | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1186519875, COSV66617825; called by muse, mutect2, varscan2
- IGKV3-15 | c.208G>T p.G70C | Missense Mutation (SNP) | VAF 21/200 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.656); catalogued as rs553971399; called by muse, mutect2, varscan2
- IGLON5 | c.469G>T p.V157L | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.14); catalogued as rs201159850, COSV54534813; called by muse, mutect2, varscan2
- IGSF10 | c.7490C>A p.T2497K | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV56370576; called by muse, mutect2, varscan2
- IGSF10 | c.3142G>T p.E1048* | Nonsense Mutation (SNP) | VAF 39/153 reads (25%) | catalogued as COSV56782276, COSV56792468; called by muse, mutect2, varscan2
- IGSF5 | c.166G>T p.A56S | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66029450; called by muse, mutect2, varscan2
- IL25 | c.149A>G p.E50G | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59304981; called by muse, mutect2
- ILF3 | c.1645G>C p.G549R | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); catalogued as COSV99139430; called by muse, mutect2, varscan2
- INSL5 | c.66C>A p.S22R | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs778970586, COSV58787976; called by muse, mutect2, varscan2
- INSRR | c.3717C>A p.F1239L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100947234; called by muse, mutect2, varscan2
- INTU | c.2455G>T p.E819* | Nonsense Mutation (SNP) | VAF 17/76 reads (22%) | catalogued as COSV58869828; called by muse, mutect2, varscan2
- IPO8 | c.3020C>A p.A1007E | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.044); catalogued as COSV56239193, COSV56239949; called by muse, mutect2, varscan2
- IPO8 | c.323+1G>T p.X108_splice | Splice Site (SNP) | VAF 38/126 reads (30%) | catalogued as COSV56239957, COSV56244872; called by muse, mutect2, varscan2
- IQGAP2 | c.98G>T p.R33L | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs369302838, COSV57168962; called by muse, mutect2, varscan2
- ISLR | c.509C>T p.T170I | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs780036106, COSV51433111; called by mutect2, varscan2
- ISOC1 | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1240441068, COSV51491188; called by muse, mutect2, varscan2
- ITGA2B | c.2077G>T p.A693S | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.802); catalogued as COSV52231435; called by muse, mutect2, varscan2
- ITIH2 | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.154); catalogued as rs141514196; called by muse, mutect2
- JMY | c.2528G>T p.R843I | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as COSV68659603; called by muse, mutect2, varscan2
- JRK | c.1411G>C p.A471P | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.03); catalogued as COSV70629562; called by muse, mutect2, varscan2
- KAT6B | c.1993+1G>T p.X665_splice | Splice Site (SNP) | VAF 9/47 reads (19%) | catalogued as COSV54743082; called by muse, mutect2, varscan2
- KATNAL1 | c.1090A>G p.I364V | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV66062713; called by muse, mutect2, varscan2
- KCNA4 | c.1896G>T p.K632N | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as COSV60250931; called by muse, mutect2, varscan2
- KCNH1 | c.514G>T p.V172L | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV55071630; called by muse, mutect2, varscan2
- KCNJ12 | c.277G>T p.A93S | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.45); catalogued as COSV59164166; called by muse, mutect2, varscan2
- KCNK6 | c.484G>T p.G162C | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54579015; called by muse, mutect2
- KDM3A | c.3685C>T p.Q1229* | Nonsense Mutation (SNP) | VAF 20/143 reads (14%) | catalogued as COSV57218054, COSV57218797; called by muse, mutect2, varscan2
- KIAA0319 | c.710C>G p.P237R | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as COSV65496762; called by muse, mutect2, varscan2
- KIAA0895 | c.472G>T p.V158L (on ENST00000297063 / NM_001100425.2; = p.V107L on NM_015314.3) | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as COSV51709169; called by muse, mutect2, varscan2
- KIAA1109 | c.12352G>T p.G4118C | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV52664312; called by muse, mutect2, varscan2
- KIAA1549L | c.1835C>A p.T612N (on ENST00000321505; = p.T909N on NM_012194.3) | Missense Mutation (SNP) | VAF 24/214 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.052); catalogued as COSV55770406; called by muse, mutect2, varscan2
- KIF27 | c.1794A>T p.R598S | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.078); catalogued as COSV52825754; called by muse, mutect2, varscan2
- KLHL1 | c.1753A>T p.S585C | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV64767887; called by muse, mutect2
- KLHL20 | c.1293G>T p.E431D | Missense Mutation (SNP) | VAF 46/180 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52940557; called by muse, mutect2, varscan2
- KLHL6 | c.1661C>G p.A554G | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); catalogued as COSV100384738, COSV58064813; called by muse, mutect2, varscan2
- KLK4 | c.285G>T p.Q95H | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV60675824, COSV60677017; called by muse, mutect2, varscan2
- KRT37 | c.869A>C p.D290A | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56657076; called by muse, mutect2
- KRT6A | c.584G>T p.W195L | Missense Mutation (SNP) | VAF 60/153 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV58104048; called by muse, mutect2, varscan2
- KRTAP10-8 | c.547G>T p.A183S | Missense Mutation (SNP) | VAF 139/483 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as COSV58166017, COSV58166627; called by muse, mutect2, varscan2
- LAMC1 | c.2042G>T p.G681V | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51133675; called by muse, mutect2, varscan2
- LAMC3 | c.1023G>T p.E341D | Missense Mutation (SNP) | VAF 18/189 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV63088959; called by muse, mutect2
- LBP | c.911C>A p.T304K | Missense Mutation (SNP) | VAF 50/191 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.627); catalogued as COSV54138968; called by muse, varscan2
- LELP1 | c.185C>A p.P62H | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64202309; called by muse, mutect2, varscan2
- LETMD1 | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.143); catalogued as COSV50396781; called by muse, mutect2, varscan2
- LGALS9 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as COSV56348141; called by muse, mutect2, varscan2
- LGI3 | c.1519G>T p.E507* | Nonsense Mutation (SNP) | VAF 14/63 reads (22%) | catalogued as COSV60443023; called by muse, mutect2, varscan2
- LHCGR | c.583A>C p.N195H | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54293448; called by muse, mutect2, varscan2
- LILRB1 | c.1631C>A p.S544* (on ENST00000427581; = p.S494* on NM_006669.6) | Nonsense Mutation (SNP) | VAF 63/218 reads (29%) | catalogued as COSV61116402; called by muse, mutect2, varscan2
- LIPK | c.111G>C p.Q37H | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV68200711; called by muse, mutect2, varscan2
- LONRF3 | c.1948G>T p.D650Y (on ENST00000371628 / NM_001031855.3; = p.D609Y on NM_024778.5) | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100504266, COSV59150402; called by muse, mutect2, varscan2
- LOXL4 | c.1172C>A p.P391H | Missense Mutation (SNP) | VAF 70/148 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV53255527; called by muse, mutect2, varscan2
- LPA | c.4865A>T p.Q1622L | Missense Mutation (SNP) | VAF 48/201 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as COSV60297972; called by muse, mutect2, varscan2
- LRAT | c.655G>T p.A219S | Missense Mutation (SNP) | VAF 45/270 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as COSV60476607; called by muse, mutect2, varscan2
- LRIT2 | c.1241G>T p.G414V | Missense Mutation (SNP) | VAF 57/131 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60565398; called by muse, mutect2, varscan2
- LRIT2 | c.1240G>T p.G414* | Nonsense Mutation (SNP) | VAF 54/125 reads (43%) | catalogued as rs199824710, COSV100258534, COSV60564499; called by muse, mutect2, varscan2
- LRPPRC | c.3015G>C p.Q1005H | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53234833; called by muse, mutect2, varscan2
- LRRC7 | c.3304A>G p.K1102E (on ENST00000651989 / NM_001370785.2; = p.K1069E on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV50417079; called by muse, mutect2, varscan2
- LTBP1 | c.1102G>T p.G368C (on ENST00000404816 / NM_206943.4; = p.G42C on NM_000627.4) | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63181350, COSV63190597; called by muse, mutect2, varscan2
- LTBP3 | c.1775C>T p.P592L | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.46); catalogued as rs1400831758, COSV57238921; called by muse, mutect2, varscan2
- LYST | c.430A>G p.R144G | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.012); catalogued as COSV67703998; called by muse, mutect2
- LZTS2 | c.1031G>T p.R344L | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV64650995; called by muse, mutect2, varscan2
- MAGEC1 | c.2095C>A p.L699I | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.063); catalogued as COSV53569035; called by muse, mutect2, varscan2
- MAPK4 | c.310G>A p.V104I | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.057); catalogued as rs763078166, COSV68541257; called by muse, mutect2, varscan2
- MAST4 | c.7411G>A p.G2471R (on ENST00000403625 / NM_001164664.2; = p.G2282R on NM_015183.3) | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); catalogued as rs1379777873, COSV55117583; called by muse, mutect2
- MCPH1 | c.2107C>T p.R703C | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761698331, COSV60910693; called by muse, mutect2, varscan2
- MEF2C | c.373G>T p.D125Y | Missense Mutation (SNP) | VAF 38/182 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100425521, COSV60926486; called by muse, mutect2, varscan2
- MEP1A | c.2179G>T p.A727S | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.334); catalogued as COSV57918341; called by muse, mutect2, varscan2
- METTL4 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV55247144; called by muse, mutect2, varscan2
- MGAM | c.3422C>A p.S1141Y | Missense Mutation (SNP) | VAF 65/159 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV72073861; called by muse, mutect2, varscan2
- MICAL3 | c.3970G>T p.V1324L | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.079); catalogued as COSV71588069; called by muse, mutect2, varscan2
- MLYCD | c.298G>T p.G100C | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.263); catalogued as COSV52304185; called by mutect2, varscan2
- MMP10 | c.1088G>T p.R363I | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV54245588; called by muse, mutect2, varscan2
- MMP9 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.997); catalogued as COSV64884321; called by muse, mutect2, varscan2
- MNDA | c.742C>A p.H248N | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.4); catalogued as COSV63740075; called by muse, mutect2, varscan2
- MRGPRX3 | c.548G>A p.W183* | Nonsense Mutation (SNP) | VAF 24/182 reads (13%) | catalogued as COSV66933290; called by muse, mutect2, varscan2
- MRPL30 | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.299); catalogued as rs773756100, COSV57666628; called by mutect2, varscan2
- MSLN | c.705-2A>T p.X235_splice | Splice Site (SNP) | VAF 7/44 reads (16%) | catalogued as COSV53499669; called by muse, mutect2, varscan2
- MUC16 | c.33710C>A p.S11237* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as COSV67449711; called by muse, mutect2, varscan2
- MUC2 | c.433C>A p.L145I | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.094); catalogued as rs1488053760; called by muse, mutect2, varscan2
- MUC21 | c.953C>A p.S318Y | Missense Mutation (SNP) | VAF 39/310 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as rs748992183, COSV100888839; called by muse, mutect2, varscan2
- MUSK | c.2500C>A p.L834I | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51878545; called by muse, mutect2, varscan2
- MXRA5 | c.2410T>G p.L804V | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54226312; called by muse, mutect2
- MYB | c.1828C>A p.P610T | Missense Mutation (SNP) | VAF 56/171 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV57196289; called by muse, mutect2, varscan2
- MYH1 | c.4809C>A p.S1603R | Missense Mutation (SNP) | VAF 78/242 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV56844561; called by muse, varscan2
- MYO16 | c.4987C>A p.P1663T | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); catalogued as COSV100696154, COSV62745178; called by muse, mutect2, varscan2
- MYO1D | c.394G>T p.E132* | Nonsense Mutation (SNP) | VAF 27/91 reads (30%) | catalogued as COSV59008301; called by muse, mutect2, varscan2
- MYO1G | c.628G>C p.G210R | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV51853360; called by muse, mutect2, varscan2
- NAGPA | c.1058G>T p.R353L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | PolyPhen benign (0.097); catalogued as COSV56569394; called by muse, mutect2
- NBAS | c.5139-1G>T p.X1713_splice | Splice Site (SNP) | VAF 11/45 reads (24%) | catalogued as COSV55714223; called by muse, mutect2, varscan2
- NBAS | c.4349G>T p.G1450V | Missense Mutation (SNP) | VAF 23/208 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55714234; called by muse, mutect2, varscan2
- NBEA | c.3233C>A p.P1078Q | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.26); catalogued as COSV59764301; called by muse, mutect2, varscan2
- NCAN | c.1292C>A p.P431H | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.436); catalogued as COSV99386721; called by muse, mutect2, varscan2
- NCAPH | c.455A>G p.K152R | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53635256; called by muse, mutect2
- NCKAP5 | c.858G>T p.E286D | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV58430583; called by muse, mutect2
- NDST4 | c.1814C>G p.T605R | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52110805; called by muse, mutect2, varscan2
- NEDD4 | c.2735A>G p.N912S (on ENST00000508342 / NM_001284338.1; = p.N493S on NM_006154.4) | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV59059163; called by muse, mutect2, varscan2
- NHSL2 | c.1930G>T p.V644L (on ENST00000510661; = p.V1010L on NM_001013627.2) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV65452562; called by muse, mutect2, varscan2
- NID1 | c.1379C>A p.S460Y | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51615832; called by muse, mutect2, varscan2
- NID1 | c.1250G>T p.G417V | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV51615849; called by muse, mutect2, varscan2
- NIPAL3 | c.802G>T p.D268Y | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50230305; called by muse, mutect2, varscan2
- NLRP14 | c.3251A>T p.E1084V | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.22); catalogued as COSV55064700; called by muse, mutect2, varscan2
- NLRP2 | c.2290G>T p.G764C | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54752874; called by muse, mutect2, varscan2
- NLRP3 | c.1051G>T p.V351L | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as CM060243, CM071606, COSV60220950; called by muse, mutect2, varscan2
- NLRP4 | c.617C>A p.S206Y | Missense Mutation (SNP) | VAF 57/164 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100015586, COSV56709094; called by muse, mutect2, varscan2
- NLRP4 | c.1267G>T p.G423W | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56709107, COSV56714256; called by mutect2, varscan2
- NMRK2 | c.376G>T p.E126* | Nonsense Mutation (SNP) | VAF 13/29 reads (45%) | catalogued as COSV51454954, COSV99396383; called by muse, mutect2, varscan2
- NMUR1 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.647); catalogued as rs775345754, COSV59403614; called by muse, mutect2, varscan2
- NNMT | c.650G>T p.G217V | Missense Mutation (SNP) | VAF 13/167 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.79); catalogued as COSV55473096; called by muse, mutect2
- NOS1AP | c.1191G>T p.E397D | Missense Mutation (SNP) | VAF 54/315 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV62632536; called by muse, mutect2, varscan2
- NOTCH4 | c.4183G>T p.D1395Y | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV66679167, COSV66679207; called by muse, mutect2, varscan2
- NPY2R | c.871G>T p.V291F | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.47); catalogued as COSV61527392; called by muse, mutect2, varscan2
- NRSN1 | c.166A>T p.R56W | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.924); catalogued as COSV65893720; called by muse, mutect2, varscan2
- NTAQ1 | c.392G>T p.R131I | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54873826, COSV54876634; called by muse, mutect2, varscan2
- NUF2 | c.276-1G>T p.X92_splice | Splice Site (SNP) | VAF 23/98 reads (23%) | catalogued as COSV54842363; called by muse, mutect2, varscan2
- NUGGC | c.1886A>G p.K629R | Missense Mutation (SNP) | VAF 45/219 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV58432892; called by muse, mutect2, varscan2
- NUGGC | c.241G>A p.G81R | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.66); catalogued as COSV58432905; called by muse, mutect2, varscan2
- NUP58 | c.121G>T p.G41W | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67750980; called by muse, mutect2, varscan2
- NYNRIN | c.430G>T p.G144C | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs775948701, COSV66841367; called by muse, mutect2, varscan2
- OBSCN | c.16484C>A p.S5495* | Nonsense Mutation (SNP) | VAF 34/187 reads (18%) | catalogued as COSV52747622; called by muse, mutect2, varscan2
- OGN | c.70C>A p.Q24K | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99363999; called by muse, mutect2, varscan2
- OR13C4 | c.779C>A p.A260E | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.442); catalogued as rs1231005102, COSV52926000; called by muse, mutect2, varscan2
- OR13C4 | c.343del p.G116Afs*2 | Frame Shift Del (DEL) | VAF 31/261 reads (12%) | catalogued as COSV52926735; called by mutect2, pindel, varscan2
- OR14A16 | c.478G>T p.G160C | Missense Mutation (SNP) | VAF 53/244 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.434); catalogued as COSV62926213; called by muse, mutect2, varscan2
- OR1N2 | c.156C>G p.I52M | Missense Mutation (SNP) | VAF 16/209 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV65460303; called by muse, mutect2
- OR2B11 | c.822G>T p.Q274H | Missense Mutation (SNP) | VAF 59/300 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV59509455; called by muse, mutect2, varscan2
- OR2C3 | c.458G>T p.G153V | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV63574549; called by muse, mutect2
- OR2G2 | c.467T>C p.I156T | Missense Mutation (SNP) | VAF 81/279 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV60739619; called by muse, mutect2, varscan2
- OR2G3 | c.753C>A p.F251L | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60680996; called by muse, mutect2, varscan2
- OR2L3 | c.549G>A p.M183I | Missense Mutation (SNP) | VAF 41/271 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as COSV63454631; called by muse, mutect2, varscan2
- OR2M7 | c.257T>A p.L86* | Nonsense Mutation (SNP) | VAF 171/557 reads (31%) | catalogued as COSV58738152; called by muse, mutect2, varscan2
- OR2M7 | c.5C>A p.A2E | Missense Mutation (SNP) | VAF 40/307 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.013); catalogued as COSV58738159; called by muse, mutect2, varscan2
- OR2T10 | c.122G>C p.W41S | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100393641, COSV57896246; called by muse, mutect2, varscan2
- OR2T34 | c.614A>T p.Y205F | Missense Mutation (SNP) | VAF 71/390 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.173); catalogued as COSV60899780, COSV60900889; called by muse, mutect2, varscan2
- OR2T8 | c.97G>T p.V33F | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs369963137, COSV60661777; called by muse, mutect2, varscan2
- OR2W3 | c.423C>G p.C141W | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64456220, COSV64456361, COSV64456545; called by muse, mutect2, varscan2
- OR4A15 | c.215C>A p.S72Y | Missense Mutation (SNP) | VAF 61/200 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.172); catalogued as COSV59033850, COSV59034664; called by muse, mutect2, varscan2
- OR4D5 | c.333G>T p.K111N | Missense Mutation (SNP) | VAF 57/159 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV58305900; called by muse, mutect2, varscan2
- OR4D6 | c.206T>C p.L69P | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV55659131; called by muse, mutect2, varscan2
- OR4D9 | c.407T>C p.M136T | Missense Mutation (SNP) | VAF 17/180 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs780860318, COSV100259730; called by muse, mutect2
- OR51Q1 | c.885T>A p.S295R | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV56178029; called by muse, mutect2
- OR52B4 | c.127G>T p.G43W | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68768633; called by muse, mutect2, varscan2
- OR52K1 | c.859C>G p.P287A | Missense Mutation (SNP) | VAF 42/204 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV56903092; called by muse, mutect2, varscan2
- OR5K3 | c.757C>A p.L253I | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.158); catalogued as COSV67349767; called by muse, mutect2, varscan2
- OR6B2 | c.7G>C p.G3R | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV68791328; called by muse, mutect2
- OR6C1 | c.127C>A p.L43I | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV101110430, COSV65572776; called by muse, mutect2, varscan2
- OR6K2 | c.190A>T p.S64C | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as COSV62743167; called by muse, mutect2, varscan2
- OR8J1 | c.550C>A p.L184M | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57316855; called by muse, mutect2, varscan2
- OSBPL6 | c.2605G>T p.A869S | Missense Mutation (SNP) | VAF 63/207 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV51912195; called by muse, mutect2, varscan2
- OTOA | c.2058+1G>T p.X686_splice (on ENST00000286149; = p.X672_splice on NM_144672.4) | Splice Site (SNP) | VAF 10/118 reads (8%) | catalogued as COSV53750157; called by muse, mutect2
- OTP | c.725C>A p.A242E | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.29); catalogued as COSV60568561; called by muse, mutect2, varscan2
- OXSM | c.1069G>T p.A357S | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.377); catalogued as COSV55000854, COSV99772001; called by muse, mutect2, varscan2
- PAK5 | c.204+1G>T p.X68_splice | Splice Site (SNP) | VAF 5/45 reads (11%) | catalogued as COSV100781169; called by muse, mutect2
- PALB2 | c.2956G>T p.D986Y | Missense Mutation (SNP) | VAF 49/195 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV55162891; called by muse, mutect2, varscan2
- PALD1 | c.871G>T p.E291* | Nonsense Mutation (SNP) | VAF 6/41 reads (15%) | catalogued as COSV54971230; called by muse, mutect2, varscan2
- PAPLN | c.800G>C p.R267P (on ENST00000554301; = p.R240P on NM_173462.4) | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.586); catalogued as COSV53724713, COSV99389246; called by muse, mutect2, varscan2
- PAPPA2 | c.215C>G p.P72R | Missense Mutation (SNP) | VAF 55/323 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV62774202; called by muse, mutect2, varscan2
- PAQR9 | c.377C>A p.A126E | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV61417691, COSV61418890; called by muse, mutect2, varscan2
- PARP8 | c.1304G>A p.S435N | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV55856668; called by muse, mutect2, varscan2
- PCDH10 | c.2843G>T p.G948V | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV52088555; called by muse, mutect2, varscan2
- PCDH17 | c.2504G>C p.S835T | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.011); catalogued as COSV64972253; called by muse, mutect2, varscan2
- PCDHB7 | c.1402C>A p.L468M | Missense Mutation (SNP) | VAF 88/272 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.856); catalogued as COSV50755814, COSV50775321; called by muse, mutect2, varscan2
- PCDHGA8 | c.767C>A p.P256H | Missense Mutation (SNP) | VAF 55/165 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs756625630, COSV53908987; called by muse, mutect2, varscan2
- PCDHGA9 | c.2157G>T p.W719C | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as COSV53909016; called by muse, mutect2, varscan2
- PCYT1B | c.611A>T p.D204V | Missense Mutation (SNP) | VAF 59/145 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV63264203; called by muse, mutect2, varscan2
- PDGFA | c.580G>T p.G194* | Nonsense Mutation (SNP) | VAF 20/348 reads (6%) | catalogued as COSV63279250; called by muse, mutect2
- PDIA2 | c.187C>A p.L63M | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.892); catalogued as COSV51984142; called by muse, mutect2, varscan2
- PDILT | c.1033G>T p.A345S | Missense Mutation (SNP) | VAF 32/219 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as rs747898472, COSV56699985, COSV56701372; called by muse, mutect2, varscan2
- PDZRN3 | c.2867G>T p.G956V | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747778714, COSV55192349, COSV99731424; called by muse, mutect2, varscan2
- PDZRN3 | c.2777G>C p.R926P | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55192373; called by muse, mutect2, varscan2
- PECR | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV54733625; called by muse, mutect2, varscan2
- PHLDA1 | c.734G>T p.R245L | Missense Mutation (SNP) | VAF 54/118 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV56996736, COSV56996832; called by muse, mutect2, varscan2
- PI4KB | c.300G>T p.E100D (on ENST00000368873 / NM_001369623.1; = p.E112D on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.584); catalogued as COSV55015593; called by muse, mutect2, varscan2
- PIK3CG | c.2391+1G>T p.X797_splice | Splice Site (SNP) | VAF 8/76 reads (11%) | catalogued as COSV100782643; called by muse, mutect2, varscan2
- PIP5K1A | c.343G>T p.V115L (on ENST00000368888 / NM_001135638.2; = p.V102L on NM_003557.3) | Missense Mutation (SNP) | VAF 51/225 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.303); catalogued as COSV62957543; called by muse, mutect2, varscan2
- PKHD1L1 | c.8535C>A p.H2845Q | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV65738596; called by muse, mutect2, varscan2
- PKNOX2 | c.1076C>A p.A359D | Missense Mutation (SNP) | VAF 44/324 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV53541886; called by muse, mutect2, varscan2
- PLB1 | c.4050C>A p.F1350L | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV59820331; called by muse, varscan2
- PLCB1 | c.3409G>T p.D1137Y | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100569763; called by muse, mutect2, varscan2
- PLCE1 | c.2575C>A p.Q859K | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.155); catalogued as COSV99593866; called by muse, mutect2, varscan2
- PLCE1 | c.2576A>G p.Q859R | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as COSV99593873; called by muse, mutect2, varscan2
- PLEC | c.11719G>A p.G3907S (on ENST00000322810 / NM_201380.4; = p.G3797S on NM_000445.5) | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1444612790, COSV59609645; called by muse, mutect2, varscan2
- PLEKHG3 | c.2105A>G p.N702S (on ENST00000394691; = p.N758S on NM_001308147.2) | Missense Mutation (SNP) | VAF 56/230 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs757599300, COSV55978066; called by muse, mutect2, varscan2
- PLPPR4 | c.926A>C p.Y309S | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV64564647; called by muse, mutect2
- PLXND1 | c.4994-1G>C p.X1665_splice | Splice Site (SNP) | VAF 18/95 reads (19%) | catalogued as COSV60709986; called by muse, mutect2, varscan2
- PPP1R12B | c.915G>T p.Q305H | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61113940; called by muse, mutect2
- PPP2R1A | c.1115A>T p.Q372L | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59042818; called by muse, mutect2, varscan2
- PPP3R2 | c.402C>A p.D134E | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); catalogued as COSV62451450; called by muse, mutect2, varscan2
- PPP4R3A | c.2336G>T p.G779V (on ENST00000554943 / NM_001366432.1; = p.G766V on NM_001284280.1) | Missense Mutation (SNP) | VAF 36/231 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.127); catalogued as COSV61503680; called by muse, mutect2, varscan2
- PRAMEF19 | c.1141A>G p.T381A | Missense Mutation (SNP) | VAF 86/647 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); catalogued as rs763111416; called by muse, mutect2, varscan2
- PRDM16 | c.1870G>T p.D624Y | Missense Mutation (SNP) | VAF 28/231 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV54580933, COSV54607748, COSV54607942; called by muse, mutect2, varscan2
- PRDM5 | c.1657G>A p.A553T | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.61); catalogued as COSV53356651; called by muse, mutect2, varscan2
- PRELP | c.83C>A p.P28H | Missense Mutation (SNP) | VAF 54/175 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.436); catalogued as COSV58115097, COSV58116639; called by muse, mutect2, varscan2
- PRKCB | c.528C>A p.L176= | Splice Region (SNP) | VAF 20/113 reads (18%) | catalogued as COSV57768867; called by muse, mutect2, varscan2
- PRKD1 | c.536G>T p.G179V | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59560745; called by muse, mutect2, varscan2
- PROC | c.549T>A p.C183* | Nonsense Mutation (SNP) | VAF 25/92 reads (27%) | catalogued as COSV52164948; called by muse, mutect2, varscan2
- PRPF38B | c.559-1G>T p.X187_splice | Splice Site (SNP) | VAF 36/95 reads (38%) | catalogued as COSV64223543; called by muse, mutect2, varscan2
- PRPS1L1 | c.373A>T p.I125F | Missense Mutation (SNP) | VAF 68/216 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV72649831; called by muse, mutect2, varscan2
- PSD | c.1417G>C p.A473P | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as COSV50042276, COSV50065773; called by muse, mutect2, varscan2
- PSEN1 | c.320C>T p.T107I | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99997660; called by muse, mutect2
- PSG7 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 67/509 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.594); catalogued as rs775658996, COSV68444433; called by muse, mutect2, varscan2
- PTAFR | c.865G>T p.D289Y | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59536158, COSV59536571; called by muse, mutect2, varscan2
- PTCHD4 | c.2074G>C p.V692L | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.84); catalogued as COSV59778280, COSV59779193; called by muse, mutect2, varscan2
- PTGFR | c.722G>C p.R241T | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.047); catalogued as COSV66114511, COSV66116048; called by muse, mutect2, varscan2
- PTGFRN | c.1847T>C p.L616P | Missense Mutation (SNP) | VAF 32/196 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as COSV67797915; called by muse, mutect2, varscan2
- PTPRD | c.3745C>A p.P1249T | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV61931781; called by muse, mutect2
- PTPRZ1 | c.658C>G p.L220V | Missense Mutation (SNP) | VAF 67/203 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1029352780, COSV66431656; called by muse, mutect2, varscan2
- PUM2 | c.1679G>A p.G560D | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57578403; called by muse, mutect2, varscan2
- PUM3 | c.1189-1G>T p.X397_splice | Splice Site (SNP) | VAF 11/58 reads (19%) | catalogued as COSV67395793; called by muse, mutect2, varscan2
- PYDC1 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.863); catalogued as COSV57251708; called by muse, mutect2, varscan2
- QTRT1 | c.682G>C p.G228R | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748388439, COSV51550332, COSV99139017; called by muse, mutect2, varscan2
- R3HDM1 | c.794A>T p.K265I | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51521501; called by muse, mutect2, varscan2
- RAB3C | c.377C>A p.T126N | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.902); catalogued as COSV51432144; called by muse, mutect2, varscan2
- RAB3GAP2 | c.149del p.G50Efs*41 | Frame Shift Del (DEL) | VAF 19/136 reads (14%) | catalogued as COSV52966745; called by mutect2, pindel, varscan2
- RABGEF1 | c.776G>T p.R259L (on ENST00000439720 / NM_001287061.2; = p.R246L on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV53161033; called by muse, mutect2, varscan2
- RABL3 | c.463A>T p.T155S | Missense Mutation (SNP) | VAF 67/340 reads (20%) | SIFT tolerated (0.79); PolyPhen benign (0.023); catalogued as COSV56335162; called by muse, mutect2, varscan2
- RAG1 | c.2683G>T p.V895L | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV55024101; called by muse, mutect2
- RALGPS2 | c.949G>T p.A317S | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.045); catalogued as COSV100243628; called by muse, mutect2, varscan2
- RANGAP1 | c.534G>T p.K178N | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.266); catalogued as COSV62362614; called by muse, mutect2, varscan2
- RAPGEF2 | c.3487G>T p.V1163L | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV52425451; called by muse, mutect2, varscan2
- RAPGEF3 | c.848G>T p.W283L (on ENST00000389212; = p.W241L on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50198845; called by muse, mutect2, varscan2
- RASGRF2 | c.1996C>A p.L666M | Missense Mutation (SNP) | VAF 86/388 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54124012; called by muse, varscan2
- RASSF2 | c.581G>T p.R194L | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369276882, COSV65081772; called by muse, mutect2, varscan2
- RBBP6 | c.1632G>C p.R544S | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.987); catalogued as COSV60503656; called by muse, mutect2, varscan2
- RBM47 | c.481A>T p.M161L | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV55930810; called by muse, mutect2, varscan2
- RBM7 | c.436G>T p.V146L | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.236); catalogued as rs1197876807, COSV64955434; called by muse, mutect2, varscan2
- RCC2 | c.7A>T p.R3W | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.035); catalogued as COSV64905359; called by muse, mutect2, varscan2
- RDH16 | c.940G>T p.A314S | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.142); catalogued as COSV100660177, COSV62457935; called by muse, mutect2, varscan2
- REC114 | c.680C>A p.S227Y | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV58521596; called by muse, mutect2, varscan2
- REG3A | c.374G>T p.S125I | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.129); catalogued as COSV59408670; called by muse, mutect2, varscan2
- RFC3 | c.661A>T p.R221* | Nonsense Mutation (SNP) | VAF 12/60 reads (20%) | catalogued as COSV66296524; called by muse, mutect2, varscan2
- RGS22 | c.2123A>G p.Y708C | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760394259, COSV62658145; called by muse, mutect2, varscan2
- RGS7BP | c.327C>G p.I109M | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); catalogued as COSV61833723; called by muse, mutect2, varscan2
- RHOJ | c.151G>A p.V51M | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as rs921202045, COSV57456941; called by muse, mutect2, varscan2
- RICTOR | c.4258G>T p.G1420C | Missense Mutation (SNP) | VAF 45/269 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV57118145, COSV57121123; called by muse, mutect2, varscan2
- RICTOR | c.172G>T p.G58C | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV57118160, COSV99704618; called by muse, mutect2, varscan2
- RIMS1 | c.379G>T p.G127W | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53442305, COSV53450164; called by muse, mutect2, varscan2
- RIPOR2 | c.1906G>C p.D636H | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV52418052; called by muse, mutect2
- RNF151 | c.489G>T p.E163D | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.551); catalogued as COSV58399304; called by muse, mutect2, varscan2
- ROR2 | c.1821del p.S608Afs*15 | Frame Shift Del (DEL) | VAF 21/101 reads (21%) | catalogued as COSV65219314; called by mutect2, pindel, varscan2
- RP1 | c.1572T>G p.D524E | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV55111517; called by muse, mutect2
- RPS6KL1 | c.845G>T p.R282M | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.19); catalogued as COSV63580733; called by muse, mutect2, varscan2
- RSPO2 | c.199G>T p.G67W | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52639444; called by muse, mutect2, varscan2
- RTTN | c.5312C>T p.T1771I | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as COSV55342008; called by muse, mutect2
- RUVBL1 | c.141G>T p.E47D | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV59475136; called by muse, mutect2, varscan2
- SAMHD1 | c.1090C>T p.H364Y | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.068); catalogued as rs761616206, COSV53428585; called by muse, mutect2, varscan2
- SCAF11 | c.2711G>T p.G904V | Missense Mutation (SNP) | VAF 102/218 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV65475262; called by muse, mutect2, varscan2
- SCG2 | c.739G>T p.G247* | Nonsense Mutation (SNP) | VAF 83/268 reads (31%) | catalogued as COSV100544872, COSV59539229; called by muse, mutect2, varscan2
- SCN1A | c.2509G>T p.G837C (on ENST00000303395 / NM_001202435.3; = p.G826C on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.026); catalogued as COSV57662590; called by muse, mutect2, varscan2
- SCN9A | c.2822A>T p.Q941L (on ENST00000303354; = p.Q930L on NM_002977.3) | Missense Mutation (SNP) | VAF 63/323 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); catalogued as COSV57602235; called by muse, mutect2, varscan2
- SCRN1 | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 19/341 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV54128723; called by muse, mutect2
- SCRN1 | c.622G>C p.A208P | Missense Mutation (SNP) | VAF 55/331 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54128739; called by muse, mutect2, varscan2
- SDK1 | c.3625G>T p.V1209L | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV67358609; called by muse, mutect2, varscan2
- SEC13 | c.258G>C p.W86C (on ENST00000350697 / NM_183352.3; = p.W89C on NM_030673.4) | Missense Mutation (SNP) | VAF 48/159 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61601343, COSV61602328; called by muse, mutect2, varscan2
- SEC31A | c.3500C>A p.T1167N (on ENST00000355196 / NM_001318120.1; = p.T1128N on NM_016211.4) | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as COSV52342095; called by muse, mutect2, varscan2
- SEMA3A | c.926A>G p.Q309R | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.08); catalogued as COSV54863214, COSV54870165; called by muse, mutect2, varscan2
- SERPINA9 | c.151T>A p.F51I | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54073061; called by muse, varscan2
- SERPINA9 | c.38G>C p.G13A | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.391); catalogued as COSV54073079; called by muse, varscan2
- SERPINB12 | c.504T>A p.G168= | Splice Region (SNP) | VAF 18/140 reads (13%) | catalogued as COSV54032267; called by muse, mutect2, varscan2
- SERTAD2 | c.307G>T p.A103S | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.054); catalogued as COSV57639728; called by muse, mutect2, varscan2
- SETBP1 | c.3815G>C p.S1272T | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as COSV56314588; called by muse, varscan2
- SEZ6L2 | c.1209-1G>A p.X403_splice (on ENST00000308713 / NM_001114099.3; = p.X333_splice on NM_012410.4) | Splice Site (SNP) | VAF 12/59 reads (20%) | catalogued as rs769341834, COSV58097601; called by muse, mutect2, varscan2
- SH3GL3 | c.301G>T p.G101W | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs559656402, COSV61053890, COSV61056992; called by muse, varscan2
- SHOC1 | c.89C>A p.T30N | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.018); catalogued as COSV59498205; called by muse, mutect2, varscan2
- SHPRH | c.2378G>C p.R793P | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV51605525; called by muse, mutect2, varscan2
- SHROOM4 | c.3566G>A p.G1189D | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV56785390; called by muse, mutect2
- SIGLEC10 | c.2062C>T p.Q688* | Nonsense Mutation (SNP) | VAF 31/116 reads (27%) | catalogued as COSV59479537; called by muse, mutect2, varscan2
- SIGLEC8 | c.121C>A p.L41M | Missense Mutation (SNP) | VAF 42/179 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV58472444; called by muse, mutect2, varscan2
- SIGLEC9 | c.794G>T p.G265V | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51582875; called by muse, mutect2, varscan2
- SKAP2 | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 8/54 reads (15%) | catalogued as COSV61721770; called by muse, mutect2, varscan2
- SLC10A2 | c.346G>T p.A116S | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.129); catalogued as COSV55357451; called by muse, mutect2
- SLC10A7 | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.186); catalogued as COSV53880821; called by muse, mutect2, varscan2
- SLC12A1 | c.391C>A p.L131M | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57708450; called by muse, mutect2, varscan2
- SLC12A5 | c.1004C>T p.T335M (on ENST00000454036 / NM_001134771.2; = p.T312M on NM_020708.5) | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs780957586, COSV54789531; called by muse, mutect2
- SLC17A9 | c.368T>C p.F123S | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as rs1283808937, COSV64846909; called by muse, mutect2
- SLC22A6 | c.683A>T p.Y228F | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.253); catalogued as COSV64559895; called by muse, mutect2, varscan2
- SLC30A3 | c.371G>A p.W124* | Nonsense Mutation (SNP) | VAF 31/111 reads (28%) | catalogued as COSV51984206; called by muse, mutect2, varscan2
- SLC43A2 | c.1704C>A p.F568L | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.084); catalogued as COSV56767848, COSV56772073; called by muse, mutect2
- SLC44A1 | c.1585G>T p.V529L | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.997); catalogued as COSV58262544; called by muse, mutect2, varscan2
- SLC4A3 | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.707); catalogued as rs766023938, COSV56091989; called by muse, mutect2, varscan2
- SLC5A11 | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 41/319 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61740384; called by muse, mutect2, varscan2
- SLC5A7 | c.29C>A p.A10D | Missense Mutation (SNP) | VAF 40/194 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV50889271; called by muse, mutect2, varscan2
- SLC6A19 | c.653C>T p.T218I | Missense Mutation (SNP) | VAF 29/181 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58669857; called by muse, mutect2, varscan2
- SLC6A5 | c.712G>T p.A238S | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.593); catalogued as COSV54224033, COSV54224296; called by muse, mutect2, varscan2
- SLCO2B1 | c.985C>A p.P329T | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as COSV56933378; called by muse, mutect2, varscan2
- SLIT1 | c.2080G>A p.G694R | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56581393; called by muse, mutect2, varscan2
- SLITRK6 | c.1355C>A p.P452Q | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV68389526; called by muse, mutect2
- SMARCA4 | c.4015G>T p.E1339* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as COSV60788531, COSV60806990; called by muse, mutect2, varscan2
- SMARCAD1 | c.3020G>T p.G1007V | Missense Mutation (SNP) | VAF 69/257 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV62773170; called by muse, mutect2, varscan2
- SMC4 | c.349A>T p.S117C | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58445575; called by muse, mutect2, varscan2
- SMOC1 | c.1205G>T p.R402L | Missense Mutation (SNP) | VAF 53/311 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs1455506717, COSV62759766, COSV62760557; called by muse, mutect2, varscan2
- SMURF1 | c.1918T>G p.L640V | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62815787; called by muse, mutect2, varscan2
- SNIP1 | c.910G>T p.A304S | Missense Mutation (SNP) | VAF 27/202 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56165765; called by muse, mutect2, varscan2
- SORCS3 | c.982C>G p.R328G | Missense Mutation (SNP) | VAF 86/201 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV100865177, COSV63803722; called by muse, mutect2, varscan2
- SPEF2 | c.1535G>T p.G512V | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV61544933; called by muse, mutect2, varscan2
- SPEG | c.7937G>T p.R2646L | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs201143360, COSV56664385, COSV56671387; called by muse, mutect2, varscan2
- SPN | c.99G>T p.L33F | Missense Mutation (SNP) | VAF 41/177 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.423); catalogued as COSV64070009; called by muse, mutect2, varscan2
- SPRR1B | c.195C>A p.C65* | Nonsense Mutation (SNP) | VAF 65/319 reads (20%) | catalogued as COSV61067471; called by muse, mutect2, varscan2
- SPTBN1 | c.6790G>T p.V2264L | Missense Mutation (SNP) | VAF 36/265 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.12); catalogued as COSV61686131; called by muse, mutect2, varscan2
- SPTBN2 | c.901A>T p.M301L | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs897181468, COSV59448114; called by muse, mutect2, varscan2
- SQSTM1 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.122); catalogued as COSV62434318; called by muse, mutect2, varscan2
- SRGAP2 | c.1646C>T p.A549V (on ENST00000624873 / NM_001170637.4; = p.A550V on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV55333992; called by muse, mutect2, varscan2
- SRGAP2 | c.3161G>T p.G1054V (on ENST00000624873 / NM_001170637.4; = p.G1055V on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 80/257 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.101); catalogued as COSV55334005; called by muse, mutect2, varscan2
- STARD13 | c.839G>T p.R280L (on ENST00000336934 / NM_001243476.3; = p.R162L on NM_052851.3) | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as COSV55227890; called by muse, mutect2, varscan2
- STARD13 | c.464G>T p.R155L (on ENST00000336934 / NM_001243476.3; = p.R37L on NM_052851.3) | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV55227681, COSV55227908; called by muse, mutect2, varscan2
- STARD7 | c.841G>C p.E281Q | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV61525174; called by muse, mutect2, varscan2
- STEAP4 | c.182G>A p.G61D | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.172); catalogued as COSV57328271; called by muse, mutect2, varscan2
- STIM1 | c.1183C>T p.H395Y | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV56152127; called by muse, mutect2, varscan2
- STK31 | c.2473C>A p.P825T | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63454440; called by muse, mutect2, varscan2
- STPG2 | c.1369G>A p.D457N | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); catalogued as COSV54787871; called by muse, mutect2
- STXBP1 | c.235C>G p.P79A | Missense Mutation (SNP) | VAF 22/203 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs1462181047, COSV64812224; called by muse, mutect2, varscan2
- SULT2A1 | c.716T>A p.V239E | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.457); catalogued as COSV55764269; called by muse, mutect2, varscan2
- SYNPO2 | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs914334727, COSV61107476; called by muse, mutect2, varscan2
- SYNPO2 | c.2045G>T p.G682V | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61107491; called by muse, mutect2, varscan2
- SYTL2 | c.252A>T p.A84= | Splice Region (SNP) | VAF 73/225 reads (32%) | catalogued as COSV60356417; called by muse, mutect2, varscan2
- TAF1L | c.1792G>T p.G598C | Missense Mutation (SNP) | VAF 54/291 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54259118, COSV99644232; called by muse, mutect2, varscan2
- TAF1L | c.1791G>T p.Q597H | Missense Mutation (SNP) | VAF 55/297 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.18); catalogued as COSV54262769, COSV99644233; called by muse, mutect2, varscan2
- TAS1R1 | c.2439C>A p.Y813* | Nonsense Mutation (SNP) | VAF 17/98 reads (17%) | catalogued as COSV59839437; called by muse, mutect2, varscan2
- TBX22 | c.79C>A p.P27T | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV64785128; called by muse, mutect2, varscan2
- TBX3 | c.1069G>T p.A357S (on ENST00000257566 / NM_016569.4; = p.A337S on NM_005996.4) | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated (0.76); PolyPhen benign (0.124); catalogued as COSV57469656; called by muse, mutect2, varscan2
- TBX5 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 13/165 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV59858835; called by muse, mutect2
- TCEA2 | c.76G>T p.G26* | Nonsense Mutation (SNP) | VAF 12/165 reads (7%) | catalogued as COSV58657286; called by muse, mutect2
- TCF7L2 | c.1319-2A>T p.X440_splice (on ENST00000355995 / NM_001367943.1; = p.X417_splice on NM_030756.5) | Splice Site (SNP) | VAF 12/77 reads (16%) | catalogued as COSV99525401; called by muse, mutect2, varscan2
- TENM2 | c.1729C>A p.P577T (on ENST00000518659 / NM_001122679.2; = p.P345T on NM_001080428.3) | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.14); catalogued as COSV69124046; called by muse, mutect2, varscan2
- TENM4 | c.2570G>T p.C857F | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV53612327; called by muse, mutect2, varscan2
- TESPA1 | c.889C>T p.R297* (on ENST00000316577 / NM_001098815.3; = p.R159* on NM_014796.2 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 35/78 reads (45%) | catalogued as rs764857918, COSV57257521; called by muse, mutect2, varscan2
- TET1 | c.5352G>T p.K1784N | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1454252323, COSV65382496; called by muse, mutect2
- TET1 | c.5698G>T p.G1900C | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65382501; called by muse, mutect2
- TEX13B | c.245A>T p.Q82L | Missense Mutation (SNP) | VAF 63/125 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57202254; called by muse, mutect2, varscan2
- TEX2 | c.1798G>T p.E600* | Nonsense Mutation (SNP) | VAF 55/171 reads (32%) | catalogued as COSV51978037; called by muse, mutect2, varscan2
- TFAP2B | c.212C>A p.P71Q | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV53825533; called by muse, mutect2, varscan2
- TFPT | c.13C>G p.Q5E | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV58084653; called by muse, mutect2, varscan2
- TG | c.3398A>G p.E1133G | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.419); catalogued as COSV55067050; called by muse, mutect2
- TG | c.7620C>A p.Y2540* | Nonsense Mutation (SNP) | VAF 65/188 reads (35%) | catalogued as COSV55067077; called by muse, mutect2, varscan2
- TGFBR3 | c.2278G>T p.E760* | Nonsense Mutation (SNP) | VAF 43/140 reads (31%) | catalogued as COSV53022438; called by muse, mutect2, varscan2
- TGM4 | c.1597C>A p.Q533K | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.05); catalogued as COSV56092980; called by muse, mutect2, varscan2
- TGM7 | c.46A>T p.S16C | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.923); catalogued as COSV71772602; called by muse, mutect2, varscan2
- THSD7A | c.1596G>T p.Q532H | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as COSV70261105; called by muse, mutect2, varscan2
- TIGD4 | c.457G>T p.G153C | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV100427862, COSV58549072; called by muse, mutect2, varscan2
- TIMELESS | c.3454G>T p.E1152* | Nonsense Mutation (SNP) | VAF 142/350 reads (41%) | catalogued as COSV57509473; called by muse, mutect2, varscan2
- TKTL2 | c.989C>A p.A330D | Missense Mutation (SNP) | VAF 45/191 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54917715, COSV54919539; called by muse, mutect2, varscan2
- TLL1 | c.1963A>T p.R655* | Nonsense Mutation (SNP) | VAF 35/130 reads (27%) | catalogued as COSV50263459, COSV50321640; called by muse, mutect2, varscan2
- TNC | c.3435T>G p.Y1145* | Nonsense Mutation (SNP) | VAF 31/373 reads (8%) | catalogued as COSV60781231; called by muse, mutect2
- TOPORS | c.277G>C p.V93L | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.202); catalogued as COSV62116305; called by muse, mutect2, varscan2
- TP53 | c.217del p.V73Wfs*50 | Frame Shift Del (DEL) | VAF 74/252 reads (29%) | catalogued as CD109812, COSV53023392, COSV53359933, COSV53361901, COSV53625318, COSV99409681; called by mutect2, varscan2
- TPO | c.2656G>A p.E886K | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.156); catalogued as COSV61096265; called by muse, mutect2, varscan2
- TRAM1 | c.135A>T p.K45N | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as COSV51596845; called by muse, mutect2, varscan2
- TRAM1L1 | c.442G>T p.D148Y | Missense Mutation (SNP) | VAF 41/186 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as COSV60291369; called by muse, mutect2, varscan2
- TRANK1 | c.8203G>A p.G2735S | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as rs765419817, COSV57143035, COSV57160597; called by muse, mutect2, varscan2
- TRIB2 | c.1001T>A p.M334K | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.87); PolyPhen benign (0.05); catalogued as COSV99330952; called by muse, mutect2, varscan2
- TRIB2 | c.1002G>T p.M334I | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV50223936, COSV99330959; called by muse, mutect2, varscan2
- TRIM55 | c.1236G>A p.Q412= | Splice Region (SNP) | VAF 25/98 reads (26%) | catalogued as COSV99396586; called by muse, mutect2, varscan2
- TRIM55 | c.1236+1G>T p.X412_splice | Splice Site (SNP) | VAF 24/95 reads (25%) | catalogued as COSV52545690, COSV99396591; called by muse, mutect2, varscan2
- TRIM71 | c.2449C>T p.R817W | Missense Mutation (SNP) | VAF 18/245 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67470262; called by muse, mutect2
- TRIM75P | c.1316C>A p.T439N | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.421); catalogued as COSV72295808; called by muse, mutect2, varscan2
- TRIML1 | c.1386C>A p.C462* | Nonsense Mutation (SNP) | VAF 30/139 reads (22%) | catalogued as COSV60193516; called by muse, mutect2, varscan2
- TRMT2B | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 73/160 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.635); catalogued as COSV58618627; called by muse, mutect2, varscan2
- TRPM4 | c.2953G>T p.V985L | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV53259986; called by muse, mutect2, varscan2
- TRPV5 | c.758C>A p.T253N | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as COSV54683514; called by muse, mutect2, varscan2
- TSPAN33 | c.581C>A p.P194H | Missense Mutation (SNP) | VAF 133/379 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.2); catalogued as COSV56825583; called by muse, mutect2, varscan2
- TXNDC12 | c.463C>T p.Q155* | Nonsense Mutation (SNP) | VAF 13/109 reads (12%) | catalogued as COSV65412962; called by muse, mutect2, varscan2
- UCMA | c.376G>T p.G126C | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66321313, COSV66321927; called by muse, mutect2, varscan2
- UGDH | c.166G>T p.G56* | Nonsense Mutation (SNP) | VAF 13/89 reads (15%) | catalogued as COSV57096859; called by muse, mutect2, varscan2
- UGT2A1 | c.72G>T p.L24F | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54138765; called by muse, mutect2, varscan2
- UGT2A3 | c.827G>A p.G276E | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52359053; called by muse, mutect2, varscan2
- ULK4 | c.1799C>A p.A600D | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.021); catalogued as COSV57200805; called by muse, mutect2
- UMOD | c.139G>T p.V47F | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV56774007; called by muse, varscan2
- UMODL1 | c.1411G>T p.V471L | Missense Mutation (SNP) | VAF 62/244 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.079); catalogued as rs150059583, COSV61159437; called by muse, mutect2, varscan2
- UNC13C | c.2645T>A p.M882K | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.261); catalogued as COSV52848094; called by muse, mutect2, varscan2
- UNC5B | c.782G>T p.R261L | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.939); catalogued as COSV58974958; called by muse, mutect2, varscan2
- UPRT | c.823G>T p.G275C | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64920006; called by muse, mutect2, varscan2
- USF3 | c.4761C>A p.N1587K | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.138); catalogued as COSV57070355; called by muse, mutect2, varscan2
- USH2A | c.6949G>T p.G2317C | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56335022; called by muse, mutect2, varscan2
- USH2A | c.1493C>A p.T498N | Missense Mutation (SNP) | VAF 57/196 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.062); catalogued as COSV56335038; called by muse, mutect2, varscan2
- USHBP1 | c.463G>A p.G155R | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.659); catalogued as rs528877755, COSV53102475; called by muse, mutect2, varscan2
- USP34 | c.5315G>T p.R1772M | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as COSV68398936; called by mutect2, varscan2
- USP6 | c.1735G>A p.G579R | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51476237; called by muse, mutect2, varscan2
- USP8 | c.272G>T p.G91V | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56162742; called by muse, mutect2, varscan2
- VCAN | c.8380G>C p.E2794Q | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.223); catalogued as rs1258524498, COSV54098501; called by muse, mutect2
- VPS13C | c.2662A>G p.T888A (on ENST00000644861 / NM_020821.3; = p.T845A on NM_017684.5) | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV51126776; called by muse, mutect2, varscan2
- VPS16 | c.217G>T p.G73C | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66792615; called by muse, mutect2, varscan2
- VPS35 | c.305G>C p.G102A | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as COSV54477333; called by muse, mutect2, varscan2
- VSNL1 | c.531C>A p.S177R | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.019); catalogued as COSV54597763; called by muse, mutect2, varscan2
- VSTM2A | c.238G>T p.G80C | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.813); catalogued as COSV56492534; called by muse, mutect2, varscan2
- VSTM2A | c.372A>T p.L124F | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56492547; called by muse, mutect2, varscan2
- VWA5A | c.1625+1G>C p.X542_splice | Splice Site (SNP) | VAF 20/170 reads (12%) | catalogued as COSV64412069; called by muse, mutect2, varscan2
- VWF | c.2974G>T p.V992L | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54613271; called by muse, mutect2, varscan2
- WARS2 | c.136A>G p.I46V | Missense Mutation (SNP) | VAF 50/355 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV52476213; called by muse, mutect2, varscan2
- WDR27 | c.189G>T p.Q63H | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61205048; called by muse, mutect2, varscan2
- WDR36 | c.1610-1G>T p.X537_splice | Splice Site (SNP) | VAF 5/28 reads (18%) | catalogued as COSV72605091; called by muse, mutect2
- WT1 | c.643C>G p.P215A | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.075); catalogued as COSV100187314; called by muse, mutect2
- YARS2 | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV61401423; called by muse, mutect2, varscan2
- YIPF7 | c.529G>T p.G177C | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60656114; called by muse, mutect2, varscan2
- ZAN | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.035); catalogued as rs369072360, COSV61805765; called by muse, mutect2, varscan2
- ZAN | c.2306C>A p.S769Y | Missense Mutation (SNP) | VAF 87/295 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV61805831; called by muse, mutect2, varscan2
- ZBED4 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV53464082; called by muse, mutect2, varscan2
- ZBTB21 | c.2044C>A p.L682I | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.963); catalogued as COSV60403299, COSV60404906; called by muse, mutect2
- ZC3H6 | c.2663C>G p.P888R | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV59666282; called by muse, mutect2, varscan2
- ZEB1 | c.2380C>T p.P794S | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as rs963030640, COSV100313658, COSV58037936; called by muse, mutect2, varscan2
- ZFHX4 | c.7613T>C p.M2538T | Missense Mutation (SNP) | VAF 39/269 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV50550614; called by muse, mutect2, varscan2
- ZFPM2 | c.2114A>G p.H705R | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65872742; called by muse, mutect2, varscan2
- ZMYND11 | c.1307T>C p.V436A | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.164); catalogued as COSV59076674; called by muse, mutect2, varscan2
- ZNF236 | c.2173G>T p.G725C | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV53483373; called by muse, mutect2, varscan2
- ZNF236 | c.5334C>G p.Y1778* | Nonsense Mutation (SNP) | VAF 12/83 reads (14%) | catalogued as COSV53483061, COSV53483402; called by muse, mutect2, varscan2
- ZNF268 | c.1137G>T p.Q379H | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as COSV99934759; called by muse, mutect2
- ZNF268 | c.1138A>T p.K380* | Nonsense Mutation (SNP) | VAF 3/12 reads (25%) | catalogued as COSV99934762; called by muse, mutect2
- ZNF285 | c.940A>T p.K314* | Nonsense Mutation (SNP) | VAF 17/154 reads (11%) | catalogued as COSV58408173; called by muse, mutect2
- ZNF292 | c.2751G>T p.L917F | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.188); catalogued as COSV60536307; called by muse, mutect2, varscan2
- ZNF536 | c.2821C>A p.L941M | Missense Mutation (SNP) | VAF 10/279 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.44); catalogued as COSV62819691; called by muse, mutect2
- ZNF592 | c.571G>C p.V191L | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.061); catalogued as COSV55435363; called by muse, mutect2, varscan2
- ZNF683 | c.1252C>G p.R418G (on ENST00000403843; = p.R398G on NM_173574.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV62873582, COSV62874562; called by muse, mutect2, varscan2
- ZNF713 | c.198G>T p.E66D (on ENST00000633730 / NM_001366796.2; = p.E79D on NM_182633.3) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV68887878; called by muse, mutect2, varscan2
- ZNF804B | c.1635G>T p.W545C | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.818); catalogued as COSV60818633; called by muse, mutect2, varscan2
- ZNF831 | c.1175C>A p.A392E | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756694854, COSV64037437; called by muse, varscan2
- ZNF831 | c.4238C>G p.T1413S | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as COSV64037978; called by muse, mutect2, varscan2
- ZP1 | c.307G>T p.V103L | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.333); catalogued as COSV53923401, COSV53923449; called by muse, mutect2, varscan2
- ZSCAN18 | c.527G>T p.G176V | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as COSV53730179; called by muse, mutect2, varscan2
- ACVR2A | c.1310dup p.R438Efs*19 | Frame Shift Ins (INS) | VAF 34/117 reads (29%) | called by mutect2, varscan2
- AHNAK2 | c.16224del p.T5409Lfs*2 | Frame Shift Del (DEL) | VAF 18/68 reads (26%) | called by mutect2, pindel, varscan2
- AHNAK2 | c.5152del p.Q1718Rfs*5 | Frame Shift Del (DEL) | VAF 38/344 reads (11%) | called by mutect2, varscan2
- BIRC6 | c.4685_4693del p.E1562_P1565delinsA | In Frame Del (DEL) | VAF 21/200 reads (11%) | called by mutect2, pindel, varscan2
- CYP26A1 | c.641dup p.E215Rfs*119 | Frame Shift Ins (INS) | VAF 24/134 reads (18%) | called by pindel, varscan2
- FCGBP | c.814C>A p.Q272K | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- FNBP4 | c.343del p.D115Tfs*13 | Frame Shift Del (DEL) | VAF 41/154 reads (27%) | called by mutect2, pindel, varscan2
- FRG2C | c.703G>T p.V235F | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); called by muse, mutect2
- HP1BP3 | c.1204G>T p.G402W | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHG1 | c.672G>C p.G224= | Splice Region (SNP) | VAF 88/193 reads (46%) | called by muse, mutect2, varscan2
- IGKV1-33 | c.38T>A p.L13Q | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- IGKV2D-24 | c.194C>A p.P65Q | Missense Mutation (SNP) | VAF 49/316 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- LILRA6 | c.640C>G p.L214V | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MIXL1 | c.502del p.T168Rfs*4 | Frame Shift Del (DEL) | VAF 53/181 reads (29%) | called by mutect2, pindel, varscan2
- MUC5B | c.10047del p.S3350Pfs*13 | Frame Shift Del (DEL) | VAF 8/53 reads (15%) | called by mutect2, pindel, varscan2
- PRH2 | c.362C>A p.P121H | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- RSPH10B | c.184del p.Q62Kfs*17 | Frame Shift Del (DEL) | VAF 12/98 reads (12%) | called by mutect2, varscan2
- RTL4 | c.801_802delinsA p.P268Qfs*60 | Frame Shift Del (DEL) | VAF 46/163 reads (28%) | called by pindel, varscan2*
- SAMD9L | c.465del p.K155Nfs*2 | Frame Shift Del (DEL) | VAF 41/189 reads (22%) | called by mutect2, pindel, varscan2
- SLC6A9 | c.24dup p.M9Dfs*141 | Frame Shift Ins (INS) | VAF 57/535 reads (11%) | called by mutect2, pindel, varscan2
- SPATA31A3 | c.491A>C p.D164A | Missense Mutation (SNP) | VAF 54/490 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.017); called by muse, mutect2
- STAB2 | c.5294dup p.L1765Ffs*29 | Frame Shift Ins (INS) | VAF 62/163 reads (38%) | called by mutect2, pindel, varscan2
- SUPT20HL2 | c.1044G>T p.W348C | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- TLL2 | c.522dup p.S175Efs*7 | Frame Shift Ins (INS) | VAF 7/47 reads (15%) | called by mutect2, pindel, varscan2
- TRAV12-2 | c.42G>C p.Q14H | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TRAV13-1 | c.301C>A p.P101T | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- TRAV22 | c.88G>T p.D30Y | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- TRBV4-2 | c.53C>A p.P18H | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- VPS13B | c.7232_7245del p.I2411Rfs*23 | Frame Shift Del (DEL) | VAF 21/133 reads (16%) | called by mutect2, pindel, varscan2
- WDR35 | c.2616_2617del p.C872* (on ENST00000345530 / NM_001006657.2; = p.C861* on NM_020779.4) | Nonsense Mutation (DEL) | VAF 12/76 reads (16%) | called by pindel, varscan2
- ZBTB17 | c.2038G>A p.V680M | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- ZFHX3 | c.536dup p.K180Qfs*30 | Frame Shift Ins (INS) | VAF 10/91 reads (11%) | called by mutect2, pindel, varscan2
- ZNF831 | c.1126del p.E376Rfs*158 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by pindel, varscan2
- ADCY8 | c.3126C>A p.A1042= | Silent (SNP) | VAF 12/103 reads (12%) | catalogued as COSV53898358, COSV53911273; called by muse, mutect2, varscan2
- ADPRHL1 | c.72G>A p.K24= | Silent (SNP) | VAF 21/104 reads (20%) | catalogued as COSV60260782; called by muse, mutect2, varscan2
- AFF1 | c.1716G>T p.R572= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV100320262; called by muse, mutect2, varscan2
- AGBL1 | c.2272C>A p.R758= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV66850612, COSV66852202; called by muse, mutect2, varscan2
- ALDH1L1 | c.744G>C p.T248= | Silent (SNP) | VAF 20/110 reads (18%) | catalogued as COSV56411317, COSV56415451; called by muse, varscan2
- ANO6 | c.2056C>T p.L686= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as COSV57657696; called by muse, mutect2, varscan2
- APOB | c.3144C>A p.T1048= | Silent (SNP) | VAF 9/105 reads (9%) | catalogued as COSV51925700; called by muse, mutect2
- ARHGAP6 | c.1761C>A p.I587= | Silent (SNP) | VAF 37/90 reads (41%) | catalogued as COSV57292426, COSV57304386; called by muse, mutect2, varscan2
- ARHGEF28 | c.2484A>T p.A828= | Silent (SNP) | VAF 23/147 reads (16%) | catalogued as COSV55248680; called by muse, mutect2, varscan2
- ASB10 | c.672G>T p.R224= (on ENST00000420175 / NM_001142459.2; = p.R209= on NM_080871.4) | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV51994634, COSV51997282; called by muse, mutect2, varscan2
- ASB15 | c.324C>A p.T108= | Silent (SNP) | VAF 37/169 reads (22%) | catalogued as COSV99306298; called by muse, mutect2, varscan2
- B3GNT7 | c.381G>C p.P127= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV55005970; called by muse, mutect2, varscan2
- BBS9 | c.2262G>A p.A754= (on ENST00000242067 / NM_001348036.1; = p.A714= on NM_014451.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as rs751886707, COSV54158541; called by muse, mutect2
- BEND2 | c.1188C>A p.G396= | Silent (SNP) | VAF 35/66 reads (53%) | catalogued as COSV66215217, COSV66215543; called by muse, mutect2, varscan2
- BLK | c.300C>A p.L100= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs745823355, COSV99376900; called by muse, mutect2, varscan2
- BNIP2 | c.765A>T p.T255= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as COSV51105222; called by muse, mutect2, varscan2
- BOD1L1 | c.2568T>C p.G856= | Silent (SNP) | VAF 6/71 reads (8%) | catalogued as COSV50007350; called by muse, mutect2
- BPIFB1 | c.93C>T p.L31= | Silent (SNP) | VAF 19/112 reads (17%) | catalogued as rs766101557, COSV53605360; called by muse, mutect2, varscan2
- BRINP3 | c.396G>T p.G132= | Silent (SNP) | VAF 41/179 reads (23%) | catalogued as COSV66515015; called by muse, mutect2, varscan2
- C1QB | c.141C>A p.P47= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV59245084; called by muse, mutect2, varscan2
- C9orf131 | c.3216C>A p.P1072= | Silent (SNP) | VAF 76/290 reads (26%) | catalogued as COSV56609850; called by muse, mutect2, varscan2
- C9orf72 | c.951G>A p.Q317= | Silent (SNP) | VAF 19/204 reads (9%) | catalogued as rs758101832, COSV66154527, COSV66154584; called by muse, mutect2
- CALHM2 | c.9C>A p.A3= | Silent (SNP) | VAF 58/130 reads (45%) | catalogued as COSV53294521; called by muse, mutect2, varscan2
- CD109 | c.294A>T p.A98= | Silent (SNP) | VAF 33/111 reads (30%) | catalogued as COSV54646080; called by muse, mutect2, varscan2
- CD22 | c.2220C>A p.A740= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as rs1389878115, COSV50049863, COSV50055705; called by muse, mutect2, varscan2
- CHD5 | c.4951C>T p.L1651= | Silent (SNP) | VAF 18/180 reads (10%) | catalogued as rs751895497, COSV52409119; called by muse, mutect2
- CNTN2 | c.807C>A p.P269= | Silent (SNP) | VAF 19/109 reads (17%) | catalogued as rs926391066, COSV59348457; called by muse, mutect2, varscan2
- CNTN6 | c.1980A>C p.A660= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV63163799; called by muse, mutect2, varscan2
- COBL | c.1209G>T p.T403= | Silent (SNP) | VAF 36/127 reads (28%) | catalogued as COSV54339823, COSV54353011; called by muse, mutect2, varscan2
- COL22A1 | c.1431C>A p.S477= | Silent (SNP) | VAF 49/124 reads (40%) | catalogued as COSV57326454; called by muse, mutect2, varscan2
- COL3A1 | c.3381G>A p.Q1127= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as COSV58582992; called by muse, mutect2, varscan2
- CPED1 | c.2838A>T p.L946= | Silent (SNP) | VAF 48/199 reads (24%) | catalogued as rs760984728, COSV100120268; called by muse, mutect2, varscan2
- CRAMP1 | c.1245G>T p.V415= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as rs1039586551, COSV99245706; called by muse, mutect2, varscan2
- CSH2 | c.372C>G p.A124= | Silent (SNP) | VAF 18/98 reads (18%) | catalogued as COSV100400163; called by muse, mutect2, varscan2
- CSMD3 | c.2877A>T p.S959= (on ENST00000297405 / NM_001363185.1; = p.S855= on NM_052900.3) | Silent (SNP) | VAF 6/98 reads (6%) | catalogued as COSV52116045; called by muse, mutect2
- CYB561A3 | c.222G>C p.G74= | Silent (SNP) | VAF 26/99 reads (26%) | catalogued as COSV53651009; called by muse, mutect2, varscan2
- DACH2 | c.390C>A p.I130= | Silent (SNP) | VAF 23/42 reads (55%) | catalogued as COSV64163065; called by muse, mutect2, varscan2
- DUSP15 | c.87A>T p.T29= (on ENST00000278979 / NM_001320479.1; = p.T32= on NM_080611.4) | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as COSV54065122; called by muse, mutect2, varscan2
- EIF3F | c.171G>T p.A57= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV100562501; called by muse, mutect2, varscan2
- ELOVL3 | c.453A>T p.T151= | Silent (SNP) | VAF 89/223 reads (40%) | catalogued as COSV64174185; called by muse, mutect2, varscan2
- ENTR1 | c.520C>T p.L174= (on ENST00000357365 / NM_001039707.2; = p.L151= on NM_006643.4) | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV53740759; called by muse, mutect2, varscan2
- ERI3 | c.33G>A p.G11= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV64830366; called by muse, mutect2
- ERN2 | c.1155A>G p.A385= | Silent (SNP) | VAF 29/166 reads (17%) | catalogued as COSV56831909; called by muse, mutect2, varscan2
- ESR1 | c.828C>A p.G276= | Silent (SNP) | VAF 38/141 reads (27%) | catalogued as rs1296595449, COSV52783514; called by muse, mutect2, varscan2
- FAM135B | c.681C>T p.Y227= | Silent (SNP) | VAF 29/200 reads (15%) | catalogued as COSV52709185; called by muse, mutect2, varscan2
- FAM210A | c.573T>C p.Y191= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as rs756626265, COSV59183560; called by muse, mutect2, varscan2
- FAM71D | c.1056C>T p.T352= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as COSV61294783; called by muse, mutect2, varscan2
- FAT3 | c.4860A>T p.L1620= | Silent (SNP) | VAF 79/209 reads (38%) | catalogued as COSV53082578; called by muse, mutect2, varscan2
- FCRLA | c.252G>A p.Q84= (on ENST00000367959; = p.Q61= on NM_032738.4) | Silent (SNP) | VAF 34/106 reads (32%) | catalogued as COSV52684637; called by muse, varscan2
168 further variants in this file (0 protein-altering or splice-affecting, 150 silent, 18 other) are not listed here.
